Somatic mutation profile of tumor specimen C3L-07082-02 (aliquot CPT0412920006) from CPTAC case C3L-07082, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 69.9 years (25,537 days).
Specimen C3L-07082-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78ad29d7-5170-4fc9-98e3-f6fbc267bf4b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07082-31 (Blood Derived Normal), aliquot CPT0413060002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/750b5cb7-a514-465b-b6e5-2edfee446ef4

The open-access MAF lists 1,938 somatic variants for this specimen: 1,418 protein-altering or splice-affecting, 447 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 898, Silent 447, Frame Shift Del 357, Frame Shift Ins 71, Nonsense Mutation 53, Intron 41, In Frame Del 15, Splice Site 14, 3'UTR 13, Splice Region 8, 5'UTR 6, 5'Flank 6.

Variants (750 of 1,938; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.10131dup p.Q3378Tfs*12 | Frame Shift Ins (INS) | VAF 54/383 reads (14%) | catalogued as rs1553416867; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- B3GALT6 | c.588del p.R197Afs*81 | Frame Shift Del (DEL) | VAF 99/593 reads (17%) | catalogued as rs533071750, COSV55420617; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CFTR | c.2502del p.F834Lfs*10 | Frame Shift Del (DEL) | VAF 21/142 reads (15%) | catalogued as rs397508389, COSV50077164; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CHD2 | c.3734del p.K1245Nfs*4 | Frame Shift Del (DEL) | VAF 34/180 reads (19%) | catalogued as rs752940775; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 65/420 reads (15%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FLNB | c.1592dup p.H532Tfs*9 | Frame Shift Ins (INS) | VAF 66/339 reads (19%) | catalogued as rs746105983; ClinVar: pathogenic; called by mutect2, varscan2
- LIFR | c.1578del p.K526Nfs*4 | Frame Shift Del (DEL) | VAF 36/203 reads (18%) | catalogued as rs1554020702; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- LTBP3 | c.2216del p.G739Afs*7 | Frame Shift Del (DEL) | VAF 41/320 reads (13%) | catalogued as rs752375653, CD153951; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MFRP | c.3del p.H2Tfs*100 (on ENST00000449574; = p.H384Tfs*94 on NM_031433.4) | Frame Shift Del (DEL) | VAF 40/276 reads (14%) | catalogued as rs587776595; ClinVar: pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 29/226 reads (13%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- NKX6-2 | c.234del p.L79Cfs*109 | Frame Shift Del (DEL) | VAF 73/506 reads (14%) | catalogued as rs765650727; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- PCCB | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 49/299 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); catalogued as rs751538672, CM146343; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SUFU | c.71del p.P24Rfs*72 | Frame Shift Del (DEL) | VAF 38/257 reads (15%) | catalogued as rs587776579; ClinVar: pathogenic; called by mutect2, varscan2
- TNNI3 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 50/319 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs727504275, CM050764, COSV52571327, COSV52572563; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- TOP3A | c.2271dup p.R758Qfs*3 | Frame Shift Ins (INS) | VAF 66/456 reads (14%) | catalogued as rs752838075; ClinVar: pathogenic; called by mutect2, varscan2
- AC068580.4 | c.716C>T p.A239V | Missense Mutation (SNP) | VAF 35/315 reads (11%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.242); catalogued as rs759564989, COSV104377109; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACACA | c.556C>T p.R186C | Missense Mutation (SNP) | VAF 51/378 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762978162; called by muse, mutect2, varscan2
- ACADL | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.007); catalogued as rs377053022; called by muse, mutect2, varscan2
- ACCSL | c.893C>A p.P298H | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV101122234; called by muse, mutect2
- ACIN1 | c.3359del p.P1120Hfs*110 | Frame Shift Del (DEL) | VAF 38/264 reads (14%) | catalogued as rs756288275; called by mutect2, pindel
- ACR | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 50/373 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1272231856, COSV53361263; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 74/226 reads (33%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTSL5 | c.1387C>T p.R463C | Missense Mutation (SNP) | VAF 40/483 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs766234741, COSV57861210; called by muse, mutect2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 24/223 reads (11%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB1 | c.436C>T p.R146W | Missense Mutation (SNP) | VAF 131/715 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs564993919; called by muse, mutect2, varscan2
- ADGRB1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 86/683 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60093232; called by muse, mutect2, varscan2
- ADGRB1 | c.2696del p.P899Rfs*34 | Frame Shift Del (DEL) | VAF 27/186 reads (15%) | catalogued as rs1554616325; called by pindel, varscan2
- ADGRB1 | c.4066C>T p.R1356W | Missense Mutation (SNP) | VAF 64/672 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1189520914, COSV60101878; called by muse, mutect2
- ADGRB2 | c.1514C>T p.T505M | Missense Mutation (SNP) | VAF 58/696 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs374037147, COSV104377092; called by muse, mutect2
- ADRA2A | c.314C>T p.S105L | Missense Mutation (SNP) | VAF 85/525 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV54527065; called by muse, mutect2, varscan2
- ADRA2B | c.362A>G p.N121S | Missense Mutation (SNP) | VAF 36/675 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs375435216; called by muse, mutect2
- ADRA2C | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 26/404 reads (6%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1369280633, COSV100342544; called by muse, mutect2
- ADTRP | c.160C>T p.Q54* | Nonsense Mutation (SNP) | VAF 43/312 reads (14%) | catalogued as rs748563096; called by muse, mutect2, varscan2
- AFAP1L1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 17/298 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.642); catalogued as rs1309162883; called by muse, mutect2
- AGAP2 | c.3320C>T p.T1107M (on ENST00000547588 / NM_001122772.2; = p.T751M on NM_014770.4) | Missense Mutation (SNP) | VAF 66/427 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as rs1230008281, COSV99224614; called by muse, mutect2, varscan2
- AGAP3 | c.1135G>A p.G379S (on ENST00000622464; = p.G415S on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/371 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (1); catalogued as rs535196546; called by muse, mutect2, varscan2
- AGAP3 | c.2264G>A p.R755Q (on ENST00000622464; = p.R791Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/608 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.169); catalogued as rs200184291; called by muse, mutect2, varscan2
- AHCTF1 | c.553C>T p.R185* (on ENST00000366508; = p.R159* on NM_015446.5) | Nonsense Mutation (SNP) | VAF 51/426 reads (12%) | catalogued as COSV58252336; called by muse, mutect2, varscan2
- AKAP17A | c.370C>T p.R124C | Missense Mutation (SNP) | VAF 121/731 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.96); catalogued as rs763312035; called by muse, varscan2
- ALDH1L2 | c.62del p.N21Tfs*3 | Frame Shift Del (DEL) | VAF 64/339 reads (19%) | catalogued as COSV51556927; called by mutect2, pindel, varscan2
- ALS2CL | c.1363del p.Q455Sfs*83 | Frame Shift Del (DEL) | VAF 98/598 reads (16%) | catalogued as rs765143111; called by mutect2, varscan2
- AMY2B | c.103C>T p.R35* | Nonsense Mutation (SNP) | VAF 56/579 reads (10%) | catalogued as rs761465185, COSV63717172; called by muse, mutect2, varscan2
- ANGPTL1 | c.1134dup p.V379Sfs*13 | Frame Shift Ins (INS) | VAF 46/323 reads (14%) | catalogued as rs775978569; called by mutect2, pindel, varscan2
- ANKFN1 | c.1928G>A p.R643H | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766639016, COSV59443457; called by muse, mutect2, varscan2
- ANKIB1 | c.1018A>G p.I340V | Missense Mutation (SNP) | VAF 36/215 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.119); catalogued as rs766956969; called by muse, mutect2, varscan2
- ANKRD13B | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs371236478, COSV61471913; called by muse, mutect2, varscan2
- ANKRD62 | c.1439del p.K480Sfs*5 | Frame Shift Del (DEL) | VAF 18/146 reads (12%) | catalogued as rs774510795; called by mutect2, varscan2
- ANO8 | c.2120G>A p.R707H | Missense Mutation (SNP) | VAF 44/580 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.322); catalogued as rs750006508; called by muse, mutect2
- ANXA4 | c.112G>A p.A38T | Missense Mutation (SNP) | VAF 58/396 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as rs376382183; called by muse, mutect2, varscan2
- AOAH | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 66/415 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766158004, COSV99331948; called by muse, mutect2, varscan2
- AP2A1 | c.2786C>T p.A929V | Missense Mutation (SNP) | VAF 83/472 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58242521; called by muse, mutect2, varscan2
- APC2 | c.2143G>A p.V715M | Missense Mutation (SNP) | VAF 109/660 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1375414438; called by muse, mutect2, varscan2
- APEH | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 84/424 reads (20%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.786); catalogued as rs1286126689, COSV99610767; called by muse, varscan2
- APLP2 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 71/433 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53839475; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 32/192 reads (17%) | catalogued as rs772728725, COSV54066450; called by mutect2, varscan2
- ARHGAP5 | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 33/331 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs369146124; called by muse, mutect2, varscan2
- ARHGAP6 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 140/715 reads (20%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs1298271536; called by muse, mutect2, varscan2
- ARHGEF1 | c.2485C>T p.R829W | Missense Mutation (SNP) | VAF 98/440 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.328); catalogued as rs782092760; called by muse, mutect2, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 70/384 reads (18%) | catalogued as rs753865255; called by mutect2, varscan2
- ASCC3 | c.1058del p.K353Rfs*6 | Frame Shift Del (DEL) | VAF 24/180 reads (13%) | catalogued as rs1361297712; called by mutect2, pindel, varscan2
- ATP10A | c.1879A>G p.S627G | Missense Mutation (SNP) | VAF 71/424 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs749590729; called by muse, mutect2, varscan2
- ATP2B2 | c.1516G>A p.G506S (on ENST00000352432; = p.G472S on NM_001683.5) | Missense Mutation (SNP) | VAF 45/530 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs764150216; called by muse, mutect2
- ATP2B3 | c.2797G>A p.A933T | Missense Mutation (SNP) | VAF 94/492 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs376398205; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1400C>A p.P467H | Missense Mutation (SNP) | VAF 22/366 reads (6%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs919616326, COSV52353918; called by muse, mutect2
- AXIN2 | c.2062del p.L688* | Frame Shift Del (DEL) | VAF 98/622 reads (16%) | catalogued as CM067349, COSV61056020; called by mutect2, pindel, varscan2
- BCL9L | c.1448del p.P483Rfs*19 | Frame Shift Del (DEL) | VAF 71/420 reads (17%) | catalogued as rs752970264; called by pindel, varscan2
- BCL9L | c.1346del p.P449Lfs*14 | Frame Shift Del (DEL) | VAF 44/273 reads (16%) | catalogued as rs754310793, COSV52681762; called by pindel, varscan2
- BIRC6 | c.8708C>T p.P2903L | Missense Mutation (SNP) | VAF 110/517 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs192943089; called by muse, mutect2, varscan2
- BORCS8 | c.164G>A p.R55H | Missense Mutation (SNP) | VAF 76/454 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs574557636; called by muse, mutect2, varscan2
- BPIFB3 | c.980C>T p.A327V | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.028); catalogued as COSV64958323; called by muse, mutect2, varscan2
- BTBD11 | c.1357del p.L453Cfs*53 | Frame Shift Del (DEL) | VAF 53/543 reads (10%) | catalogued as rs777776928; called by mutect2, pindel, varscan2
- BTBD11 | c.1682C>T p.A561V (on ENST00000280758 / NM_001018072.2; = p.A98V on NM_001017523.2) | Missense Mutation (SNP) | VAF 63/427 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1368588123, COSV55016681; called by muse, mutect2, varscan2
- BTBD7 | c.173del p.K58Rfs*44 | Frame Shift Del (DEL) | VAF 99/407 reads (24%) | catalogued as rs752512017; called by mutect2, varscan2
- BTN3A2 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 56/657 reads (9%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs992030796, COSV100709783, COSV62688387; called by muse, mutect2
- BUB1 | c.2473C>T p.P825S | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs748392521, COSV100241651; called by muse, mutect2
- C10orf90 | c.1731A>C p.E577D | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52953509; called by muse, mutect2
- C1QA | c.361C>T p.R121W | Missense Mutation (SNP) | VAF 93/558 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as COSV65889996; called by muse, mutect2, varscan2
- C1orf159 | c.1073G>A p.R358Q (on ENST00000379339 / NM_001330306.2; = p.R176Q on NM_017891.5) | Missense Mutation (SNP) | VAF 17/514 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); catalogued as rs973799389; called by muse, mutect2
- C4orf54 | c.3095G>A p.R1032Q | Missense Mutation (SNP) | VAF 72/375 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.946); catalogued as COSV72766953; called by muse, mutect2, varscan2
- C5AR2 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 82/535 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.005); catalogued as rs759326628, COSV57257346; called by muse, mutect2, varscan2
- C8orf89 | c.457dup p.S153Kfs*24 | Frame Shift Ins (INS) | VAF 38/326 reads (12%) | catalogued as rs951061763; called by mutect2, varscan2
- CACNA1A | c.2738G>T p.S913I | Missense Mutation (SNP) | VAF 98/579 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs1248444650; called by mutect2, varscan2
- CACNA1B | c.5456C>T p.A1819V | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as rs200917554, COSV53113314, COSV53117131; called by muse, mutect2, varscan2
- CACNA1I | c.3026C>T p.A1009V | Missense Mutation (SNP) | VAF 104/512 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs979167439; called by muse, varscan2
- CACNG1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 76/405 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as rs371885900; called by muse, mutect2, varscan2
- CALD1 | c.1117G>A p.A373T | Missense Mutation (SNP) | VAF 101/687 reads (15%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.173); catalogued as rs764898963; called by muse, mutect2, varscan2
- CAPN10 | c.1141G>A p.V381I | Missense Mutation (SNP) | VAF 104/578 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs761598065, COSV54376813, COSV99550677; called by muse, mutect2, varscan2
- CBLN3 | c.206del p.P69Lfs*35 | Frame Shift Del (DEL) | VAF 112/671 reads (17%) | catalogued as rs1268177561; called by mutect2, pindel, varscan2
- CCDC158 | c.1217G>A p.R406Q | Missense Mutation (SNP) | VAF 78/403 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.99); catalogued as rs775250551, COSV66356338; called by muse, mutect2, varscan2
- CCDC166 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 115/747 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.093); catalogued as rs1554616986; called by muse, mutect2, varscan2
- CCDC88C | c.5630G>A p.R1877H | Missense Mutation (SNP) | VAF 38/652 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs747824457; called by muse, mutect2
- CCDC89 | c.412C>T p.R138C | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV57034754; called by muse, mutect2, varscan2
- CCNB1IP1 | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.006); catalogued as COSV100738676; called by muse, mutect2, varscan2
- CCT7 | c.1604G>A p.R535Q | Missense Mutation (SNP) | VAF 102/468 reads (22%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.885); catalogued as rs769701233, COSV54582798; called by muse, mutect2, varscan2
- CD1D | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs1220430860; called by muse, mutect2, varscan2
- CDH17 | c.2425C>T p.R809C | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs375914501; called by muse, mutect2, varscan2
- CDK18 | c.1456C>T p.R486* (on ENST00000506784 / NM_212503.3; = p.R456* on NM_002596.4) | Nonsense Mutation (SNP) | VAF 91/473 reads (19%) | catalogued as rs1241397677, COSV63726679; called by muse, mutect2, varscan2
- CDK3 | c.904C>T p.R302* | Nonsense Mutation (SNP) | VAF 29/276 reads (11%) | catalogued as rs775896948, COSV56913259; called by muse, mutect2, varscan2
- CEBPE | c.836del p.G279Vfs*19 | Frame Shift Del (DEL) | VAF 45/367 reads (12%) | catalogued as rs1363394381, COSV52829926; called by mutect2, pindel, varscan2
- CELF4 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 60/371 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.9); catalogued as COSV58461854; called by muse, mutect2, varscan2
- CELSR1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs980274462; called by muse, mutect2, varscan2
- CEMIP2 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 55/396 reads (14%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.601); catalogued as rs745839031; called by muse, mutect2, varscan2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 42/231 reads (18%) | catalogued as rs746479678; called by mutect2, varscan2
- CEP350 | c.8074G>A p.E2692K | Missense Mutation (SNP) | VAF 62/380 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs1369803302; called by muse, mutect2, varscan2
- CEP57 | c.785del p.K262Rfs*31 | Frame Shift Del (DEL) | VAF 22/144 reads (15%) | catalogued as rs762013265, COSV57689966; called by mutect2, varscan2
- CFAP298-TCP10L | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.815); catalogued as rs754390813, COSV99267232; called by muse, mutect2, varscan2
- CGAS | c.1184C>T p.T395M | Missense Mutation (SNP) | VAF 34/391 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376147946; called by muse, mutect2
- CHD8 | c.5968A>G p.T1990A (on ENST00000646647 / NM_001170629.2; = p.T1711A on NM_020920.4) | Missense Mutation (SNP) | VAF 22/612 reads (4%) | SIFT tolerated, low confidence (0.8); PolyPhen benign (0.011); catalogued as COSV104424339; called by muse, mutect2
- CHPF2 | c.1941del p.S648Pfs*13 | Frame Shift Del (DEL) | VAF 89/458 reads (19%) | catalogued as rs746469175; called by mutect2, pindel, varscan2
- CHRM1 | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 58/604 reads (10%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.46); catalogued as rs777030658; called by muse, mutect2
- CHRM3 | c.556G>A p.G186S | Missense Mutation (SNP) | VAF 78/493 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); catalogued as rs1180207221, COSV55083886; called by muse, mutect2, varscan2
- CHST1 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 71/451 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1354494827, COSV100346299, COSV57325184; called by muse, mutect2, varscan2
- CILP | c.3340G>A p.A1114T | Missense Mutation (SNP) | VAF 68/450 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as rs61735530; called by muse, mutect2, varscan2
- CKAP2 | c.1817del p.K606Rfs*14 (on ENST00000378037 / NM_001098525.2; = p.K605Rfs*14 on NM_018204.5) | Frame Shift Del (DEL) | VAF 24/128 reads (19%) | catalogued as rs752250702; called by mutect2, varscan2
- CLEC18B | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 40/353 reads (11%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.057); catalogued as rs1454759976; called by muse, mutect2, varscan2
- CLEC4G | c.196G>A p.G66S | Missense Mutation (SNP) | VAF 50/321 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.077); catalogued as COSV99078285; called by muse, mutect2, varscan2
- CLK3 | c.1066del p.I356Sfs*14 (on ENST00000395066 / NM_001130028.1; = p.I208Sfs*14 on NM_003992.4) | Frame Shift Del (DEL) | VAF 53/461 reads (11%) | catalogued as rs1272725768; called by mutect2, pindel, varscan2
- CLUH | c.1324del p.D442Tfs*12 (on ENST00000435359; = p.D480Tfs*12 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 77/510 reads (15%) | catalogued as rs752224729; called by mutect2, pindel, varscan2
- CNBD1 | c.1187T>C p.L396P | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV73072298, COSV73072404, COSV73073941; called by muse, mutect2, varscan2
- CNNM4 | c.1312del p.L438Sfs*41 | Frame Shift Del (DEL) | VAF 65/409 reads (16%) | catalogued as rs746879923; called by mutect2, pindel, varscan2
- CNNM4 | c.2235G>T p.E745D | Missense Mutation (SNP) | VAF 60/539 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV65660653; called by muse, mutect2, varscan2
- CNPPD1 | c.326G>A p.R109Q | Missense Mutation (SNP) | VAF 88/513 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as rs928324912; called by muse, mutect2, varscan2
- CNTN4 | c.2763G>A p.W921* | Nonsense Mutation (SNP) | VAF 44/269 reads (16%) | catalogued as rs1162703856, COSV61870498; called by muse, mutect2, varscan2
- CNTROB | c.2264C>T p.P755L | Missense Mutation (SNP) | VAF 80/515 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs377547989; called by muse, mutect2, varscan2
- COL11A1 | c.1735del p.R579Gfs*54 | Frame Shift Del (DEL) | VAF 56/309 reads (18%) | catalogued as COSV62195334; called by mutect2, varscan2
- CPAMD8 | c.1783G>A p.A595T (on ENST00000651564; = p.A548T on NM_015692.5) | Missense Mutation (SNP) | VAF 75/461 reads (16%) | SIFT tolerated (0.59); PolyPhen benign (0.012); catalogued as COSV52241179; called by muse, mutect2, varscan2
- CPSF1 | c.3110C>T p.A1037V | Missense Mutation (SNP) | VAF 56/434 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1554863342; called by muse, mutect2, varscan2
- CPXM2 | c.973C>T p.R325C | Missense Mutation (SNP) | VAF 24/204 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs747723133, COSV53864980; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 47/347 reads (14%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRELD1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 62/437 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.139); catalogued as rs755981922, CM108486, COSV55977319; called by muse, mutect2, varscan2
- CRHR2 | c.346G>T p.A116S | Missense Mutation (SNP) | VAF 64/399 reads (16%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.989); catalogued as COSV59264109; called by muse, mutect2, varscan2
- CSDE1 | c.2021G>A p.R674H (on ENST00000358528 / NM_001007553.3; = p.R643H on NM_007158.6) | Missense Mutation (SNP) | VAF 48/380 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs1306278892; called by muse, mutect2, varscan2
- CSH2 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 109/1370 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61080493; called by muse, mutect2
- CSMD1 | c.5326G>T p.G1776C (on ENST00000520002; = p.G1775C on NM_033225.6) | Missense Mutation (SNP) | VAF 37/614 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59345593; called by muse, mutect2
- CSMD3 | c.9931T>A p.S3311T (on ENST00000297405 / NM_001363185.1; = p.S3142T on NM_052900.3) | Missense Mutation (SNP) | VAF 62/386 reads (16%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV52116361; called by muse, mutect2, varscan2
- CSMD3 | c.6563C>A p.S2188Y (on ENST00000297405 / NM_001363185.1; = p.S2084Y on NM_052900.3) | Missense Mutation (SNP) | VAF 36/391 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); catalogued as COSV52108195; called by muse, mutect2
- CSNK1G2 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 73/363 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.822); catalogued as rs1056898992; called by muse, mutect2, varscan2
- D2HGDH | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 28/492 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV58320624; called by muse, mutect2
- DAPK1 | c.1345C>A p.L449I | Missense Mutation (SNP) | VAF 31/513 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV63786221; called by muse, mutect2
- DBF4B | c.200C>T p.T67M | Missense Mutation (SNP) | VAF 62/407 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.242); catalogued as rs139442134; called by muse, mutect2, varscan2
- DBR1 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 42/300 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs368152097; called by muse, mutect2, varscan2
- DCAF1 | c.2800C>T p.R934W | Missense Mutation (SNP) | VAF 102/536 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.733); catalogued as rs1308124579, COSV60040593; called by muse, mutect2, varscan2
- DCDC1 | c.1209dup p.Y404Ifs*3 | Frame Shift Ins (INS) | VAF 32/174 reads (18%) | catalogued as rs1159404116; called by mutect2, varscan2
- DDX31 | c.2499del p.K833Nfs*50 | Frame Shift Del (DEL) | VAF 50/388 reads (13%) | catalogued as COSV99707398; called by mutect2, pindel, varscan2
- DDX31 | c.1376C>T p.A459V | Missense Mutation (SNP) | VAF 59/457 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs370929391; called by muse, mutect2, varscan2
- DDX39A | c.643C>T p.R215C | Missense Mutation (SNP) | VAF 41/294 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.832); catalogued as rs758169897, COSV54390914; called by muse, mutect2, varscan2
- DDX49 | c.1391G>C p.R464P | Missense Mutation (SNP) | VAF 63/452 reads (14%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.044); catalogued as rs138056361; called by muse, mutect2, varscan2
- DENND1C | c.1222_1224del p.E408del | In Frame Del (DEL) | VAF 45/374 reads (12%) | catalogued as rs774558415; called by mutect2, pindel, varscan2
- DGKK | c.2879C>T p.A960V | Missense Mutation (SNP) | VAF 60/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1398939650; called by muse, mutect2, varscan2
- DIAPH1 | c.2108del p.P703Hfs*65 | Frame Shift Del (DEL) | VAF 22/146 reads (15%) | catalogued as rs771360300; called by mutect2, varscan2
- DIAPH3 | c.958del p.I320Lfs*20 (on ENST00000400324 / NM_001042517.2; = p.I57Lfs*20 on NM_030932.3) | Frame Shift Del (DEL) | VAF 28/188 reads (15%) | catalogued as rs755069320; called by mutect2, varscan2
- DIRAS1 | c.571G>A p.V191I | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1037528236; called by muse, mutect2, varscan2
- DISC1 | c.590del p.P197Qfs*146 | Frame Shift Del (DEL) | VAF 93/560 reads (17%) | catalogued as rs761174007; called by mutect2, pindel, varscan2
- DISP3 | c.853G>A p.A285T | Missense Mutation (SNP) | VAF 94/461 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs201224302, COSV53837232; called by muse, varscan2
- DISP3 | c.3805dup p.H1269Pfs*115 | Frame Shift Ins (INS) | VAF 51/357 reads (14%) | catalogued as rs756156984; called by mutect2, varscan2
- DLX3 | c.823G>A p.A275T | Missense Mutation (SNP) | VAF 89/490 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.435); catalogued as rs368296464; called by muse, mutect2, varscan2
- DLX5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 88/538 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV56031716; called by muse, mutect2, varscan2
- DMD | c.7570C>T p.R2524C | Missense Mutation (SNP) | VAF 32/269 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as rs886043732, COSV58906820; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH1 | c.3320G>A p.R1107Q | Missense Mutation (SNP) | VAF 97/561 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.104); catalogued as rs768977175, COSV70236423; called by muse, mutect2, varscan2
- DNAH10 | c.10217G>A p.R3406H (on ENST00000409039; = p.R3345H on NM_207437.3) | Missense Mutation (SNP) | VAF 87/502 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as rs775452835; called by muse, mutect2, varscan2
- DNAH11 | c.12824dup p.N4275Kfs*4 | Frame Shift Ins (INS) | VAF 45/240 reads (19%) | catalogued as rs751061873; called by mutect2, varscan2
- DNAH5 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 23/253 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0.041); catalogued as rs140388814; called by muse, mutect2
- DNAJC1 | c.1234A>G p.T412A | Missense Mutation (SNP) | VAF 98/492 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV65408746; called by muse, mutect2, varscan2
- DNM1 | c.2434del p.A812Rfs*76 | Frame Shift Del (DEL) | VAF 86/483 reads (18%) | catalogued as rs747024881; called by mutect2, varscan2
- DOCK1 | c.4882C>T p.R1628C | Missense Mutation (SNP) | VAF 57/402 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1336971745; called by muse, mutect2, varscan2
- DOCK6 | c.2888G>A p.R963H | Missense Mutation (SNP) | VAF 94/465 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.891); catalogued as rs772459080, COSV53918860; called by muse, mutect2, varscan2
- DOK2 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 68/499 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as rs1035827426, COSV52388962; called by muse, mutect2, varscan2
- DOK5 | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 58/372 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.045); catalogued as rs145303661; called by muse, mutect2, varscan2
- DPEP3 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 88/494 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs949561994, COSV52051202; called by muse, mutect2, varscan2
- DRD5 | c.667C>T p.R223* | Nonsense Mutation (SNP) | VAF 78/474 reads (16%) | catalogued as rs769335952, COSV58576772; called by muse, mutect2, varscan2
- DSCAML1 | c.2047del p.D683Tfs*14 (on ENST00000321322; = p.D623Tfs*14 on NM_020693.4) | Frame Shift Del (DEL) | VAF 69/462 reads (15%) | catalogued as COSV58392044; called by mutect2, pindel, varscan2
- DSCAML1 | c.1127A>G p.H376R (on ENST00000321322; = p.H316R on NM_020693.4) | Missense Mutation (SNP) | VAF 50/314 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs142156730; called by muse, mutect2, varscan2
- DTNB | c.1340del p.N447Tfs*39 | Frame Shift Del (DEL) | VAF 32/220 reads (15%) | catalogued as rs1558508797; called by mutect2, pindel, varscan2
- DYNC2I1 | c.2782G>A p.G928S | Missense Mutation (SNP) | VAF 53/339 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200797739, COSV68106902; called by muse, mutect2, varscan2
- E2F1 | c.1303del p.L435Wfs*58 | Frame Shift Del (DEL) | VAF 49/323 reads (15%) | catalogued as rs1409099723, COSV55776265; called by mutect2, pindel, varscan2
- ECEL1 | c.1477G>A p.A493T | Missense Mutation (SNP) | VAF 64/438 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as rs763859873, COSV58812582, COSV58814387, COSV58814488; called by muse, varscan2
- ECEL1 | c.305G>A p.R102H | Missense Mutation (SNP) | VAF 92/546 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.63); catalogued as rs746935576; called by muse, mutect2, varscan2
- EDEM2 | c.919G>A p.V307M | Missense Mutation (SNP) | VAF 96/510 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs769742867; called by muse, mutect2, varscan2
- EFTUD2 | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 65/405 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.957); catalogued as rs1393171446, COSV68185085; called by muse, mutect2, varscan2
- EIF2AK4 | c.2567dup p.L856Ffs*4 | Frame Shift Ins (INS) | VAF 36/246 reads (15%) | catalogued as rs35250897; called by mutect2, varscan2
- EIF4G1 | c.3632C>T p.T1211M (on ENST00000346169 / NM_198241.3; = p.T1016M on NM_004953.5) | Missense Mutation (SNP) | VAF 37/420 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as rs1035604616, COSV59990086; called by muse, mutect2
- EIF5A | c.292T>C p.Y98H | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.138); catalogued as COSV59747029; called by muse, mutect2
- ELAPOR1 | c.1309G>A p.V437I | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.345); catalogued as rs757611417; called by muse, mutect2, varscan2
- ELMO1 | c.22G>A p.V8I | Missense Mutation (SNP) | VAF 59/449 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.132); catalogued as COSV60316446; called by muse, mutect2, varscan2
- ELMO2 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 54/364 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.757); catalogued as rs1295726035; called by muse, mutect2, varscan2
- ELOA2 | c.1358C>T p.T453M | Missense Mutation (SNP) | VAF 106/599 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV55296340; called by muse, mutect2, varscan2
- EML5 | c.2317T>C p.Y773H | Missense Mutation (SNP) | VAF 28/284 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as rs776883953; called by muse, mutect2
- ENO4 | c.623del p.K208Rfs*32 (on ENST00000622726; = p.K207Rfs*32 on NM_001242699.2) | Frame Shift Del (DEL) | VAF 57/289 reads (20%) | catalogued as rs761717176; called by mutect2, varscan2
- EPS8L3 | c.710G>T p.R237M | Missense Mutation (SNP) | VAF 71/343 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.051); catalogued as rs1223695430; called by muse, mutect2, varscan2
- ERN1 | c.512G>A p.R171Q | Missense Mutation (SNP) | VAF 74/388 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.162); catalogued as rs372593820; called by muse, mutect2, varscan2
- ERP29 | c.589_591del p.K197del | In Frame Del (DEL) | VAF 92/504 reads (18%) | catalogued as rs1565989810; called by pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 99/435 reads (23%) | catalogued as rs775950025; called by mutect2, varscan2
- ETV3 | c.961C>T p.R321C | Missense Mutation (SNP) | VAF 71/373 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs779086898; called by muse, mutect2, varscan2
- EVPL | c.191T>C p.L64P | Missense Mutation (SNP) | VAF 70/428 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1426698628; called by muse, mutect2, varscan2
- EXOC3L2 | c.2326del p.L776Sfs*20 | Frame Shift Del (DEL) | VAF 121/735 reads (16%) | catalogued as COSV99374666; called by mutect2, pindel, varscan2
- F9 | c.1009G>A p.A337T | Missense Mutation (SNP) | VAF 60/423 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as CM940620, CM940621; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 84/413 reads (20%) | catalogued as rs766589051; called by mutect2, varscan2
- FAM110A | c.466G>A p.V156I | Missense Mutation (SNP) | VAF 115/604 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.071); catalogued as rs1185775717; called by muse, mutect2, varscan2
- FAM47A | c.2203G>T p.G735* | Nonsense Mutation (SNP) | VAF 53/364 reads (15%) | catalogued as COSV60499583; called by muse, mutect2, varscan2
- FAM71B | c.202C>T p.R68* | Nonsense Mutation (SNP) | VAF 63/471 reads (13%) | catalogued as rs747876535; called by muse, mutect2, varscan2
- FAM78B | c.30G>T p.K10N | Missense Mutation (SNP) | VAF 43/318 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.018); catalogued as rs1025861064; called by muse, mutect2, varscan2
- FAM83H | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 101/572 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV101186926; called by muse, mutect2, varscan2
- FAT1 | c.12907A>T p.S4303C | Missense Mutation (SNP) | VAF 60/429 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1366348482; called by mutect2, varscan2
- FBLL1 | c.472G>A p.A158T | Missense Mutation (SNP) | VAF 77/475 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); catalogued as COSV57924786; called by muse, mutect2, varscan2
- FBXO21 | c.432del p.F144Lfs*9 | Frame Shift Del (DEL) | VAF 26/167 reads (16%) | catalogued as rs772635228; called by mutect2, varscan2
- FBXO31 | c.1082G>A p.R361H | Missense Mutation (SNP) | VAF 105/588 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs187880966; called by muse, mutect2, varscan2
- FCN3 | c.51del p.P18Lfs*4 | Frame Shift Del (DEL) | VAF 58/357 reads (16%) | catalogued as rs765301683; called by mutect2, pindel, varscan2
- FER1L6 | c.3708del p.G1237Afs*10 | Frame Shift Del (DEL) | VAF 53/326 reads (16%) | catalogued as rs747094222, COSV67548414; called by mutect2, pindel, varscan2
- FGF8 | c.664C>T p.R222C (on ENST00000344255 / NM_033164.4; = p.R204C on NM_006119.6) | Missense Mutation (SNP) | VAF 84/485 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs780335350; called by muse, mutect2, varscan2
- FHL1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 107/604 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as rs752366165; called by muse, mutect2, varscan2
- FKBP9 | c.384del p.N129Ifs*10 | Frame Shift Del (DEL) | VAF 41/251 reads (16%) | catalogued as rs752076602; called by mutect2, pindel, varscan2
- FLNC | c.3703G>A p.V1235M | Missense Mutation (SNP) | VAF 69/509 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1208885010, COSV57955063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLT4 | c.1904C>T p.T635M | Missense Mutation (SNP) | VAF 78/452 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs753863393, COSV56117471; called by muse, mutect2, varscan2
- FOXA3 | c.101T>C p.M34T | Missense Mutation (SNP) | VAF 50/581 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as rs566369055; called by muse, mutect2
- FPR1 | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 73/419 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs201880162, COSV100494156; called by muse, mutect2, varscan2
- FREM2 | c.8281G>A p.A2761T | Missense Mutation (SNP) | VAF 57/336 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs752005956, COSV54849699; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 55/559 reads (10%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FSD2 | c.2194G>A p.G732R | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100575042; called by muse, mutect2
- FZD7 | c.907C>T p.H303Y | Missense Mutation (SNP) | VAF 68/437 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1341945140, COSV53811284; called by muse, mutect2, varscan2
- GAK | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 65/385 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100034126; called by muse, mutect2, varscan2
- GALT | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 54/342 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs553769637, COSV66592816; called by muse, mutect2, varscan2
- GATA5 | c.329del p.G110Afs*37 | Frame Shift Del (DEL) | VAF 89/660 reads (13%) | catalogued as rs1434141622, COSV53347528; called by mutect2, pindel, varscan2
- GBP6 | c.1760del p.N587Mfs*18 | Frame Shift Del (DEL) | VAF 52/326 reads (16%) | catalogued as rs1557544730; called by mutect2, pindel, varscan2
- GCC1 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 93/527 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.162); catalogued as COSV50001544; called by muse, mutect2, varscan2
- GCC1 | c.248_249del p.V83Gfs*2 | Frame Shift Del (DEL) | VAF 76/545 reads (14%) | catalogued as rs1457871440; called by pindel, varscan2
- GCN1 | c.5399C>T p.A1800V | Missense Mutation (SNP) | VAF 69/404 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371797364; called by muse, mutect2, varscan2
- GDF1 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 68/358 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.631); catalogued as rs1322632787; called by muse, varscan2
- GDF7 | c.682del p.R228Afs*41 | Frame Shift Del (DEL) | VAF 92/509 reads (18%) | catalogued as rs761897305; called by mutect2, varscan2
- GGA1 | c.1610G>A p.R537H | Missense Mutation (SNP) | VAF 48/596 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as rs1294008682; called by muse, mutect2
- GGT7 | c.1907A>G p.H636R | Missense Mutation (SNP) | VAF 60/449 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.266); catalogued as rs1295035332; called by muse, mutect2, varscan2
- GIMAP5 | c.890del p.F297Sfs*30 | Frame Shift Del (DEL) | VAF 34/263 reads (13%) | catalogued as rs774162620, COSV57529761, COSV57529909; called by mutect2, pindel, varscan2
- GJC2 | c.1259G>T p.R420M | Missense Mutation (SNP) | VAF 80/481 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.453); catalogued as COSV64513180; called by muse, mutect2, varscan2
- GOLGA4 | c.2864del p.K955Rfs*16 | Frame Shift Del (DEL) | VAF 33/227 reads (15%) | catalogued as rs754602522; called by mutect2, pindel, varscan2
- GPR143 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 91/453 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.278); catalogued as rs936878316, CD075433; called by muse, mutect2, varscan2
- GPR146 | c.521G>C p.R174P | Missense Mutation (SNP) | VAF 47/520 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV52465431, COSV52466314; called by muse, mutect2, varscan2
- GPR37 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 70/490 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs1218241050; called by muse, mutect2, varscan2
- GRIK2 | c.1597T>G p.F533V | Missense Mutation (SNP) | VAF 27/344 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59711574; called by muse, mutect2
- GRIK3 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 78/522 reads (15%) | SIFT tolerated (0.36); PolyPhen benign (0.273); catalogued as rs541445950, COSV66141763; called by muse, mutect2, varscan2
- GRIN1 | c.1486_1488del p.K496del | In Frame Del (DEL) | VAF 43/263 reads (16%) | catalogued as rs1231157661; called by pindel, varscan2
- GRIN2A | c.4205G>A p.R1402Q | Missense Mutation (SNP) | VAF 62/642 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs74935155, COSV100411016, COSV58053824; ClinVar: likely benign; called by muse, mutect2
- GRIN2A | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 47/527 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs367543131, COSV58042622; ClinVar: not provided / uncertain significance; called by muse, mutect2
- GRIN2B | c.3898C>T p.R1300W | Missense Mutation (SNP) | VAF 78/527 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1565453201, COSV74206505; called by muse, mutect2, varscan2
- GRIN2C | c.799G>A p.A267T | Missense Mutation (SNP) | VAF 104/603 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.028); catalogued as COSV99500778; called by mutect2, varscan2
- GRXCR1 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 61/449 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.483); catalogued as rs774798847, COSV67670638; called by muse, mutect2, varscan2
- GSC2 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 60/385 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99324088; called by muse, mutect2, varscan2
- GTF3C1 | c.5541del p.E1848Rfs*33 | Frame Shift Del (DEL) | VAF 85/537 reads (16%) | catalogued as rs763161381; called by mutect2, pindel, varscan2
- GTF3C3 | c.2566C>T p.R856* | Nonsense Mutation (SNP) | VAF 36/209 reads (17%) | catalogued as rs774688614; called by muse, mutect2, varscan2
- HAX1 | c.463del p.Q155Nfs*59 | Frame Shift Del (DEL) | VAF 79/446 reads (18%) | catalogued as COSV55172930; called by mutect2, pindel, varscan2
- HCN4 | c.1796C>T p.A599V | Missense Mutation (SNP) | VAF 70/391 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs775019344, COSV56083280; called by muse, mutect2, varscan2
- HDAC4 | c.2399del p.P800Lfs*30 | Frame Shift Del (DEL) | VAF 86/532 reads (16%) | catalogued as rs748900140; called by mutect2, pindel, varscan2
- HECTD2 | c.1144del p.I382Sfs*11 | Frame Shift Del (DEL) | VAF 29/198 reads (15%) | catalogued as rs57105282; called by mutect2, varscan2
- HERC2 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 50/608 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); catalogued as rs376524441; called by muse, mutect2
- HID1 | c.2318del p.P773Lfs*8 | Frame Shift Del (DEL) | VAF 65/435 reads (15%) | catalogued as COSV60913992; called by mutect2, pindel, varscan2
- HIF1AN | c.180G>A p.E60= | Splice Region (SNP) | VAF 35/210 reads (17%) | catalogued as rs1278640747; called by muse, mutect2, varscan2
- HLA-B | c.626dup p.T211Dfs*10 | Frame Shift Ins (INS) | VAF 62/224 reads (28%) | catalogued as rs748204482, COSV69520417; called by pindel, varscan2
- HNRNPL | c.1010del p.P337Hfs*58 | Frame Shift Del (DEL) | VAF 88/408 reads (22%) | catalogued as rs767148651; called by mutect2, varscan2
- HOXC12 | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 78/418 reads (19%) | SIFT tolerated (0.64); PolyPhen benign (0.173); catalogued as rs1291614710; called by muse, mutect2, varscan2
- HOXD12 | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 54/676 reads (8%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.908); catalogued as rs1413609020; called by muse, mutect2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 88/506 reads (17%) | catalogued as rs770632206; called by mutect2, varscan2
- HPGDS | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 50/326 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs779912724; called by muse, mutect2, varscan2
- HS3ST4 | c.38C>T p.P13L | Missense Mutation (SNP) | VAF 42/303 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs922018317; called by muse, mutect2, varscan2
- HSF1 | c.840del p.G281Afs*4 | Frame Shift Del (DEL) | VAF 65/454 reads (14%) | catalogued as COSV60047281; called by mutect2, pindel, varscan2
- ICAM4 | c.38dup p.L13Ffs*17 | Frame Shift Ins (INS) | VAF 64/372 reads (17%) | catalogued as rs753968171; called by mutect2, varscan2
- ICE1 | c.3731C>T p.S1244L | Missense Mutation (SNP) | VAF 43/297 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs370101868; called by muse, mutect2, varscan2
- IFIT2 | c.815del p.K272Rfs*3 | Frame Shift Del (DEL) | VAF 32/240 reads (13%) | catalogued as COSV51078943; called by mutect2, pindel, varscan2
- IGFN1 | c.3605C>T p.A1202V (on ENST00000295591 / NM_001367841.1; = p.A3659V on NM_001164586.2) | Missense Mutation (SNP) | VAF 101/609 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.115); catalogued as rs372174499; called by muse, mutect2, varscan2
- IGSF8 | c.479del p.P160Qfs*15 | Frame Shift Del (DEL) | VAF 94/539 reads (17%) | catalogued as rs754902711; called by mutect2, pindel, varscan2
- IL1RAPL1 | c.1027C>T p.R343* | Nonsense Mutation (SNP) | VAF 45/337 reads (13%) | catalogued as rs1475549924, COSV56258619; called by muse, mutect2, varscan2
- IMPA2 | c.542C>T p.A181V | Missense Mutation (SNP) | VAF 85/436 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs369840633; called by muse, mutect2, varscan2
- INF2 | c.2188G>A p.V730M | Missense Mutation (SNP) | VAF 88/482 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.09); catalogued as rs373199310; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- INMT | c.763A>G p.I255V | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as rs1217881139; called by muse, mutect2, varscan2
- INPP5E | c.1105G>T p.G369C | Missense Mutation (SNP) | VAF 65/359 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV65497316; called by muse, mutect2, varscan2
- INSR | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 67/463 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1568470274, CM025912; called by muse, mutect2, varscan2
- IPO11 | c.1152G>A p.W384* | Nonsense Mutation (SNP) | VAF 26/136 reads (19%) | catalogued as rs760805988; called by muse, mutect2, varscan2
- IRX5 | c.890C>T p.A297V | Missense Mutation (SNP) | VAF 70/406 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1477481852; called by muse, mutect2, varscan2
- ITPR2 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 50/405 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as rs752387178; called by muse, mutect2, varscan2
- JAK1 | c.1289del p.P430Rfs*2 | Frame Shift Del (DEL) | VAF 86/486 reads (18%) | catalogued as rs755650243; called by mutect2, pindel, varscan2
- JARID2 | c.1272dup p.R425Afs*99 | Frame Shift Ins (INS) | VAF 48/404 reads (12%) | catalogued as rs747291227; called by mutect2, varscan2
- KANK3 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 119/604 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as rs1216601512; called by muse, mutect2, varscan2
- KANSL1 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 112/632 reads (18%) | catalogued as rs762509401; called by muse, mutect2, varscan2
- KATNIP | c.4181C>T p.P1394L | Missense Mutation (SNP) | VAF 40/478 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as rs775676774; called by muse, mutect2
- KBTBD11 | c.1180G>A p.A394T | Missense Mutation (SNP) | VAF 70/482 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1302279221; called by muse, mutect2, varscan2
- KBTBD3 | c.1075C>T p.R359* | Nonsense Mutation (SNP) | VAF 74/413 reads (18%) | catalogued as rs200339337; called by muse, mutect2, varscan2
- KCNC2 | c.289G>A p.G97S | Missense Mutation (SNP) | VAF 95/579 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs1168781827; called by muse, mutect2, varscan2
- KCND2 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 57/480 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.14); catalogued as rs1233359609; called by muse, mutect2, varscan2
- KCNH4 | c.2397dup p.R800Qfs*33 | Frame Shift Ins (INS) | VAF 72/442 reads (16%) | catalogued as rs778022334; called by mutect2, varscan2
- KCNK17 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 92/449 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs566450809, COSV100950249; called by muse, mutect2, varscan2
- KCNK9 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 77/489 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.833); catalogued as rs779321914, COSV57288720; called by muse, mutect2, varscan2
- KCNS3 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 98/547 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as rs537401566, COSV58405721; called by muse, mutect2, varscan2
- KCNT2 | c.1500dup p.A501Cfs*2 | Frame Shift Ins (INS) | VAF 32/272 reads (12%) | catalogued as rs1249079077; called by mutect2, pindel, varscan2
- KDM3B | c.2860C>T p.R954C | Missense Mutation (SNP) | VAF 61/307 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs866179776, COSV58689822; called by muse, mutect2, varscan2
- KDM5A | c.3656G>A p.R1219Q | Missense Mutation (SNP) | VAF 72/480 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs909970288, COSV66997627; called by muse, varscan2
- KDR | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 73/434 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs551579207, COSV55757831, COSV55763620; called by muse, mutect2, varscan2
- KIAA0930 | c.876del p.T293Pfs*27 (on ENST00000336156 / NM_001009880.2; = p.T298Pfs*27 on NM_015264.2) | Frame Shift Del (DEL) | VAF 70/408 reads (17%) | catalogued as rs1294718664; called by mutect2, varscan2
- KIAA1549 | c.4427dup p.E1477Gfs*3 | Frame Shift Ins (INS) | VAF 76/482 reads (16%) | catalogued as rs752867430; called by mutect2, pindel, varscan2
- KIAA1549L | c.665C>A p.P222H (on ENST00000321505; = p.P519H on NM_012194.3) | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.338); catalogued as COSV55769942; called by muse, mutect2
- KIAA2013 | c.1316G>A p.C439Y | Missense Mutation (SNP) | VAF 95/544 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1003002266; called by muse, mutect2, varscan2
- KIF19 | c.2901del p.N968Tfs*62 | Frame Shift Del (DEL) | VAF 49/520 reads (9%) | catalogued as COSV63430265; called by mutect2, pindel
- KIF1C | c.3239del p.P1080Hfs*8 | Frame Shift Del (DEL) | VAF 74/376 reads (20%) | catalogued as rs753993722; called by mutect2, pindel, varscan2
- KIF26A | c.4324G>A p.E1442K | Missense Mutation (SNP) | VAF 40/690 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.269); catalogued as rs868018124, COSV100181673; called by muse, mutect2
- KIF3C | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 28/562 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.112); catalogued as COSV53101126; called by muse, mutect2
- KLK3 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 44/300 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs200006942; called by muse, varscan2
- KMT2E | c.2849A>G p.N950S | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.056); catalogued as COSV99996360; called by muse, varscan2
- KMT5C | c.124del p.L42Cfs*15 | Frame Shift Del (DEL) | VAF 60/392 reads (15%) | catalogued as rs769842795; called by pindel, varscan2
- KPNA4 | c.1235T>C p.V412A | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.308); catalogued as rs1283712965; called by muse, mutect2, varscan2
- KRT6A | c.193G>T p.G65W | Missense Mutation (SNP) | VAF 34/624 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1376405967; called by muse, mutect2
- KRT83 | c.1453G>T p.G485W | Missense Mutation (SNP) | VAF 30/500 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.41); catalogued as rs1243780460; called by muse, mutect2
- LAMA1 | c.2277G>A p.A759= | Splice Region (SNP) | VAF 52/294 reads (18%) | catalogued as rs377514465; called by muse, varscan2
- LAMA2 | c.2540G>A p.C847Y | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70353842; called by muse, mutect2, varscan2
- LAMA5 | c.10586del p.G3529Efs*5 | Frame Shift Del (DEL) | VAF 71/416 reads (17%) | catalogued as COSV99442228; called by mutect2, pindel, varscan2
- LARP1 | c.1226G>A p.R409H (on ENST00000518297 / NM_033551.3; = p.R332H on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 40/328 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.689); catalogued as rs1167652861, COSV60425950; called by muse, mutect2, varscan2
- LBHD2 | c.13dup p.R5Pfs*11 | Frame Shift Ins (INS) | VAF 86/397 reads (22%) | catalogued as rs1233865516; called by mutect2, varscan2
- LCE6A | c.200G>A p.G67D | Missense Mutation (SNP) | VAF 36/443 reads (8%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.912); catalogued as rs373828189; called by muse, mutect2
- LIG1 | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 80/480 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as rs542028224; called by muse, mutect2, varscan2
- LINGO3 | c.1100G>A p.R367H | Missense Mutation (SNP) | VAF 30/649 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.106); catalogued as rs1053537850; called by muse, mutect2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 64/361 reads (18%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LRCH4 | c.1253A>G p.Q418R | Missense Mutation (SNP) | VAF 93/488 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV59643877; called by muse, mutect2, varscan2
- LRFN4 | c.1571del p.G524Vfs*100 | Frame Shift Del (DEL) | VAF 102/682 reads (15%) | catalogued as COSV100540885; called by mutect2, pindel, varscan2
- LRP1 | c.13300C>G p.L4434V | Missense Mutation (SNP) | VAF 80/431 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54509929; called by muse, mutect2, varscan2
- LRP12 | c.1351del p.C451Afs*37 | Frame Shift Del (DEL) | VAF 65/471 reads (14%) | catalogued as rs35928649; called by mutect2, pindel, varscan2
- LRP2 | c.6373C>T p.R2125C | Missense Mutation (SNP) | VAF 43/387 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs375749752, COSV99789475; called by muse, mutect2, varscan2
- LRRK1 | c.4648G>A p.V1550M | Missense Mutation (SNP) | VAF 57/346 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as rs1378137531; called by muse, mutect2, varscan2
- LRRN4 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 118/702 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1303514639, COSV101125449; called by muse, mutect2, varscan2
- LTN1 | c.1239del p.F413Lfs*7 | Frame Shift Del (DEL) | VAF 44/295 reads (15%) | catalogued as rs1568851261; called by mutect2, pindel, varscan2
- LUZP2 | c.525G>A p.A175= | Splice Region (SNP) | VAF 33/172 reads (19%) | catalogued as rs148359334; called by muse, mutect2, varscan2
- LYN | c.327del p.E110Kfs*15 | Frame Shift Del (DEL) | VAF 20/224 reads (9%) | catalogued as rs1266824391, COSV99066642; called by mutect2, varscan2
- LZTS1 | c.348C>T p.G116= | Splice Region (SNP) | VAF 45/351 reads (13%) | catalogued as rs1303582351; called by muse, mutect2, varscan2
- MACO1 | c.306del p.F102Lfs*47 | Frame Shift Del (DEL) | VAF 27/152 reads (18%) | catalogued as rs752439249; called by mutect2, varscan2
- MACROH2A2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 58/396 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs868217028; called by muse, mutect2, varscan2
- MAFF | c.125G>A p.R42H | Missense Mutation (SNP) | VAF 117/590 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58298834; called by muse, mutect2, varscan2
- MAGEC1 | c.2576C>T p.S859F | Missense Mutation (SNP) | VAF 74/454 reads (16%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as rs781101047; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 82/450 reads (18%) | catalogued as rs752869239; called by mutect2, varscan2
- MAN1C1 | c.294C>A p.S98R | Missense Mutation (SNP) | VAF 94/617 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1464462970; called by muse, mutect2, varscan2
- MAN2A2 | c.1582del p.X528_splice | Splice Site (DEL) | VAF 39/309 reads (13%) | catalogued as rs1219552862; called by mutect2, pindel, varscan2
- MAN2B2 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 57/396 reads (14%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.728); catalogued as rs756714926, COSV99578234; called by muse, mutect2, varscan2
- MAP11 | c.790G>A p.A264T | Missense Mutation (SNP) | VAF 67/381 reads (18%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.676); catalogued as rs753834719; called by muse, mutect2, varscan2
- MAP3K7CL | c.16G>A p.A6T | Missense Mutation (SNP) | VAF 53/394 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.217); catalogued as rs942570262; called by muse, mutect2, varscan2
- MAP6 | c.503G>A p.R168H | Missense Mutation (SNP) | VAF 104/524 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs777211062; called by muse, mutect2, varscan2
- MAPK8IP2 | c.626A>G p.N209S | Missense Mutation (SNP) | VAF 52/608 reads (9%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV50497355; called by muse, mutect2
- MARCHF4 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 77/459 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); catalogued as rs1319560946; called by muse, mutect2, varscan2
- MARF1 | c.2204C>T p.A735V | Missense Mutation (SNP) | VAF 57/608 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1385219966; called by muse, mutect2
- MB21D2 | c.1467A>T p.K489N | Missense Mutation (SNP) | VAF 15/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV66661657; called by muse, mutect2
- MBOAT1 | c.776C>T p.T259M | Missense Mutation (SNP) | VAF 74/507 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs759484677; called by muse, mutect2, varscan2
- MCM2 | c.389G>A p.R130H | Missense Mutation (SNP) | VAF 74/414 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); catalogued as rs775995747; called by muse, mutect2, varscan2
- MCM2 | c.2362G>A p.E788K | Missense Mutation (SNP) | VAF 31/594 reads (5%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.763); catalogued as rs1235028296; called by muse, mutect2
- MCM7 | c.1594C>T p.R532W | Missense Mutation (SNP) | VAF 61/312 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs775586840, COSV57996442; called by muse, mutect2, varscan2
- MDH1B | c.1024C>T p.R342C | Missense Mutation (SNP) | VAF 23/227 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs780661298, COSV65590123; called by muse, mutect2, varscan2
- MDH1B | c.794C>T p.T265I | Missense Mutation (SNP) | VAF 73/508 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.313); catalogued as rs1413880769; called by muse, mutect2, varscan2
- MEAK7 | c.1177C>T p.P393S | Missense Mutation (SNP) | VAF 100/523 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as rs1385072275; called by muse, mutect2, varscan2
- MED12 | c.2450G>A p.R817H | Missense Mutation (SNP) | VAF 59/400 reads (15%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.535); catalogued as rs749801457, COSV61343388, COSV61349725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MED13L | c.5113C>T p.R1705C | Missense Mutation (SNP) | VAF 42/530 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs770772544, COSV56129550; called by muse, mutect2
- MED23 | c.2053C>T p.R685* | Nonsense Mutation (SNP) | VAF 63/303 reads (21%) | catalogued as rs200807237; called by muse, mutect2, varscan2
- MEDAG | c.206del p.G69Afs*29 | Frame Shift Del (DEL) | VAF 83/495 reads (17%) | catalogued as rs745558596; called by mutect2, pindel, varscan2
- MEF2B | c.832dup p.Q278Pfs*55 | Frame Shift Ins (INS) | VAF 52/410 reads (13%) | catalogued as rs1202792889; called by mutect2, varscan2
- MIB2 | c.839G>A p.R280Q | Missense Mutation (SNP) | VAF 92/527 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs866987962, COSV61757853; called by muse, mutect2, varscan2
- MLLT10 | c.1055G>T p.S352I | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.037); catalogued as COSV56999210; called by mutect2, varscan2
- MMEL1 | c.84del p.L29Cfs*8 | Frame Shift Del (DEL) | VAF 92/536 reads (17%) | catalogued as rs1168749408; called by pindel, varscan2
- MMP25 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 171/476 reads (36%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs985384235; called by muse, mutect2, varscan2
- MN1 | c.1237C>T p.R413W | Missense Mutation (SNP) | VAF 97/538 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1256775134; called by muse, mutect2, varscan2
- MROH5 | c.3481C>T p.R1161W | Missense Mutation (SNP) | VAF 84/588 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1048485521, COSV100267034; called by muse, mutect2, varscan2
- MSANTD2 | c.1558G>A p.G520R (on ENST00000374979 / NM_001308027.2; = p.G468R on NM_024631.4) | Missense Mutation (SNP) | VAF 52/371 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.933); catalogued as rs758969628, COSV99515636; called by muse, mutect2, varscan2
- MTA3 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 68/398 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs762473175; called by muse, varscan2
- MTARC2 | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 77/437 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1457393501; called by muse, mutect2, varscan2
- MTF2 | c.1188del p.G397Efs*6 | Frame Shift Del (DEL) | VAF 21/140 reads (15%) | catalogued as rs759847587; called by mutect2, varscan2
- MTTP | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 54/327 reads (17%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as CD993592, COSV55509800; called by muse, mutect2, varscan2
- MUC16 | c.36746G>A p.R12249H | Missense Mutation (SNP) | VAF 57/251 reads (23%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs775564548, COSV67484407; called by muse, mutect2, varscan2
- MUC2 | c.2854C>T p.R952W | Missense Mutation (SNP) | VAF 59/403 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as rs765413779; called by muse, mutect2, varscan2
- MUC4 | c.15648C>T p.I5216= (on ENST00000463781 / NM_018406.7; = p.I980= on NM_004532.6) | Splice Region (SNP) | VAF 50/331 reads (15%) | catalogued as rs199855139, COSV57804608; called by muse, mutect2, varscan2
- MUC5B | c.12259C>T p.P4087S | Missense Mutation (SNP) | VAF 146/848 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs759262182, COSV71591294; called by muse, varscan2
- MUC5B | c.14116del p.T4706Pfs*4 | Frame Shift Del (DEL) | VAF 95/661 reads (14%) | catalogued as COSV71592533; called by mutect2, pindel, varscan2
- MXRA5 | c.8374del p.Q2792Rfs*4 | Frame Shift Del (DEL) | VAF 73/578 reads (13%) | catalogued as COSV99475376; called by mutect2, pindel, varscan2
- MYH10 | c.2515A>C p.T839P | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV52611253; called by muse, mutect2, varscan2
- MYH10 | c.646C>T p.R216W | Missense Mutation (SNP) | VAF 37/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1216190856, COSV52599105; called by muse, mutect2, varscan2
- MYO15A | c.574dup p.R192Pfs*36 | Frame Shift Ins (INS) | VAF 75/519 reads (14%) | catalogued as rs1359244955; called by mutect2, pindel, varscan2
- MYO9A | c.5680A>T p.K1894* | Nonsense Mutation (SNP) | VAF 30/206 reads (15%) | catalogued as rs78631419, COSV61851473; called by muse, mutect2, varscan2
- MYORG | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 75/479 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.089); catalogued as COSV52627667; called by muse, mutect2, varscan2
- NACC2 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 114/552 reads (21%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs762695132; called by muse, mutect2, varscan2
- NAT8L | c.751G>A p.V251I | Missense Mutation (SNP) | VAF 95/523 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); catalogued as rs1211725738; called by muse, mutect2, varscan2
- NBAS | c.2551G>C p.E851Q | Missense Mutation (SNP) | VAF 68/348 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.017); catalogued as COSV55712689; called by muse, mutect2, varscan2
- NBEA | c.3362del p.N1121Mfs*9 | Frame Shift Del (DEL) | VAF 31/232 reads (13%) | catalogued as rs763376147; called by mutect2, varscan2
- NCAPD3 | c.4254G>T p.K1418N | Missense Mutation (SNP) | VAF 38/282 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs773764304; called by muse, mutect2, varscan2
- NCBP1 | c.445T>C p.F149L | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs1381870282; called by muse, mutect2, varscan2
- NCKAP5 | c.5612C>T p.A1871V | Missense Mutation (SNP) | VAF 38/386 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV58441711; called by muse, mutect2
- NEBL | c.903+1G>A p.X301_splice | Splice Site (SNP) | VAF 35/275 reads (13%) | catalogued as rs775057540, COSV101009165; called by muse, mutect2, varscan2
- NEFM | c.127G>A p.G43S | Missense Mutation (SNP) | VAF 77/584 reads (13%) | SIFT tolerated (0.39); PolyPhen benign (0.019); catalogued as rs1303334508, COSV55335080; called by muse, mutect2, varscan2
- NELFA | c.253G>A p.A85T (on ENST00000542778; = p.A74T on NM_005663.5) | Missense Mutation (SNP) | VAF 16/323 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs1252726874, COSV61605985; called by muse, mutect2
- NES | c.2495C>T p.A832V | Missense Mutation (SNP) | VAF 76/433 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs755961725, COSV63961896; called by muse, mutect2, varscan2
- NFATC3 | c.1673G>A p.G558D | Missense Mutation (SNP) | VAF 31/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60476257; called by muse, mutect2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 52/266 reads (20%) | catalogued as rs145147241; called by mutect2, varscan2
- NOBOX | c.1322del p.P441Hfs*25 | Frame Shift Del (DEL) | VAF 9/97 reads (9%) | catalogued as rs753934412; called by mutect2, pindel
- NPHP4 | c.1030C>T p.R344C | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs777428281, COSV100977163; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPR3 | c.895G>T p.D299Y | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as COSV54091034; called by muse, mutect2, varscan2
- NPRL3 | c.1484G>A p.R495H (on ENST00000611875 / NM_001077350.3; = p.R470H on NM_001039476.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 192/477 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs750844568, COSV54738163, COSV54738950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NRXN1 | c.3977C>T p.T1326M | Missense Mutation (SNP) | VAF 62/441 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs199701703, COSV60523393; called by muse, mutect2, varscan2
- NTN1 | c.604del p.V202Cfs*228 | Frame Shift Del (DEL) | VAF 69/482 reads (14%) | catalogued as COSV51480379; called by mutect2, pindel, varscan2
- NUGGC | c.1892del p.N631Ifs*3 | Frame Shift Del (DEL) | VAF 54/324 reads (17%) | catalogued as rs755498396, COSV58439694; called by mutect2, varscan2
- NUP188 | c.1802C>T p.T601M | Missense Mutation (SNP) | VAF 42/342 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs762343564; called by muse, mutect2, varscan2
- NUP188 | c.5171C>A p.S1724Y | Missense Mutation (SNP) | VAF 90/541 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV65331107; called by muse, mutect2, varscan2
- NUP214 | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 87/505 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1391858277; called by muse, mutect2, varscan2
- NYAP2 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 33/268 reads (12%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.997); catalogued as rs761168029, COSV56001990; called by muse, mutect2, varscan2
- OAS3 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 73/559 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs377277983; called by muse, mutect2, varscan2
- OCA2 | c.1841del p.K614Sfs*14 | Frame Shift Del (DEL) | VAF 45/327 reads (14%) | catalogued as CD000269; called by mutect2, pindel, varscan2
- OGT | c.612A>C p.Q204H | Missense Mutation (SNP) | VAF 73/344 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as COSV65482886; called by muse, mutect2, varscan2
- OR13F1 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 28/253 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs1564202255, COSV58251454; called by muse, mutect2, varscan2
- OR2A12 | c.193C>A p.L65M | Missense Mutation (SNP) | VAF 28/534 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68821170; called by muse, mutect2
- OR2G2 | c.392G>A p.R131H | Missense Mutation (SNP) | VAF 92/472 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV60740194, COSV60740632; called by muse, mutect2, varscan2
- OR2T11 | c.839C>A p.P280H | Missense Mutation (SNP) | VAF 81/420 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV58186076; called by muse, mutect2, varscan2
- OR2T6 | c.370G>A p.V124M | Missense Mutation (SNP) | VAF 118/789 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.298); catalogued as rs201925418, COSV63216883; called by muse, mutect2, varscan2
- OR7G2 | c.226C>A p.L76I | Missense Mutation (SNP) | VAF 89/503 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.652); catalogued as rs192332490; called by muse, mutect2, varscan2
- OSBPL8 | c.1946dup p.T650Dfs*2 | Frame Shift Ins (INS) | VAF 23/152 reads (15%) | catalogued as rs1402476998; called by mutect2, pindel, varscan2
- OSGIN2 | c.892C>T p.R298C | Missense Mutation (SNP) | VAF 68/441 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs533674331, COSV52408402; called by muse, mutect2, varscan2
- OTOGL | c.2342G>A p.C781Y (on ENST00000547103; = p.C772Y on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/404 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1477883879; called by muse, mutect2, varscan2
- OTUD6A | c.92del p.N31Tfs*52 | Frame Shift Del (DEL) | VAF 106/634 reads (17%) | catalogued as COSV57972665; called by mutect2, pindel, varscan2
- OTUD7A | c.1216C>T p.H406Y (on ENST00000307050 / NM_001382637.1; = p.H399Y on NM_130901.3) | Missense Mutation (SNP) | VAF 82/551 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61035771, COSV61038503; called by muse, mutect2, varscan2
- OVOL1 | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 54/334 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756785367; called by muse, mutect2, varscan2
- PACSIN1 | c.1171C>T p.R391W | Missense Mutation (SNP) | VAF 30/581 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99763002; called by muse, mutect2
- PAX2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 66/451 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62291289; called by muse, mutect2, varscan2
- PAX8 | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 82/444 reads (18%) | catalogued as COSV54507641; called by mutect2, varscan2
- PBRM1 | c.1726C>T p.R576C | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs965565832, COSV99969535, COSV99970671; called by muse, mutect2
- PCDH15 | c.5717dup p.N1906Kfs*26 | Frame Shift Ins (INS) | VAF 36/223 reads (16%) | catalogued as rs778380770; called by mutect2, varscan2
- PCDH7 | c.166G>A p.G56S | Missense Mutation (SNP) | VAF 42/506 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV62336029, COSV62343733; called by muse, mutect2
- PCDH8 | c.1039G>A p.V347I | Missense Mutation (SNP) | VAF 94/593 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.483); catalogued as rs778924290, COSV58812913, COSV58814995; called by muse, mutect2, varscan2
- PCDHA1 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 55/371 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65372895; called by muse, mutect2, varscan2
- PCDHA11 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 84/436 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56514278; called by muse, mutect2, varscan2
- PCDHA2 | c.1688C>A p.P563Q | Missense Mutation (SNP) | VAF 44/636 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV65369160; called by muse, mutect2
- PCDHA3 | c.832G>A p.A278T | Missense Mutation (SNP) | VAF 60/335 reads (18%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV65369243; called by muse, mutect2, varscan2
- PCDHB2 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 141/816 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.621); catalogued as COSV50571098; called by muse, mutect2, varscan2
- PCDHGA7 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 99/587 reads (17%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.025); catalogued as rs370612007; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 23/189 reads (12%) | catalogued as COSV61618667; called by mutect2, varscan2
- PCNT | c.7987C>T p.R2663C | Missense Mutation (SNP) | VAF 94/525 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as rs754927331, COSV64031497; called by muse, mutect2, varscan2
- PCNX2 | c.6319G>A p.A2107T | Missense Mutation (SNP) | VAF 90/445 reads (20%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.081); catalogued as COSV50822864; called by muse, mutect2, varscan2
- PDCD11 | c.1570del p.T524Pfs*2 | Frame Shift Del (DEL) | VAF 68/474 reads (14%) | catalogued as rs900259918; called by mutect2, pindel, varscan2
- PDGFRA | c.3040G>A p.A1014T | Missense Mutation (SNP) | VAF 68/460 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.054); catalogued as rs768291477, COSV57276941; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PERM1 | c.1688del p.P563Lfs*5 | Frame Shift Del (DEL) | VAF 91/544 reads (17%) | catalogued as rs1295381936; called by mutect2, pindel, varscan2
- PFKP | c.793del p.R265Gfs*2 | Frame Shift Del (DEL) | VAF 29/244 reads (12%) | catalogued as rs1161592176; called by mutect2, pindel, varscan2
- PGBD4 | c.1751del p.N584Ifs*21 | Frame Shift Del (DEL) | VAF 48/290 reads (17%) | catalogued as rs770560794; called by mutect2, varscan2
- PHACTR4 | c.2092C>T p.R698C (on ENST00000373839 / NM_001350159.2; = p.R708C on NM_023923.4) | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs754775218, COSV65783169; called by muse, mutect2, varscan2
- PI4KA | c.2336G>A p.R779Q | Missense Mutation (SNP) | VAF 30/354 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs756156190; called by muse, mutect2
- PIEZO2 | c.6188G>A p.G2063D | Missense Mutation (SNP) | VAF 65/511 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53295325; called by muse, mutect2, varscan2
- PINX1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 68/637 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.946); catalogued as rs199675528, COSV59110633; called by muse, mutect2, varscan2
- PITX2 | c.827C>T p.T276M (on ENST00000354925 / NM_001204397.1; = p.T283M on NM_000325.6) | Missense Mutation (SNP) | VAF 36/491 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100146295; called by muse, mutect2
- PKD1 | c.7531G>A p.A2511T | Missense Mutation (SNP) | VAF 122/389 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.352); catalogued as rs765479518, COSV99238139; called by muse, mutect2, varscan2
- PKHD1L1 | c.6563del p.G2188Efs*28 | Frame Shift Del (DEL) | VAF 53/318 reads (17%) | catalogued as rs772426616; called by mutect2, pindel, varscan2
- PKP1 | c.1621G>A p.G541S | Missense Mutation (SNP) | VAF 90/468 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs149193673; called by muse, mutect2, varscan2
- PLA2G4E | c.1991T>C p.L664P | Missense Mutation (SNP) | VAF 69/435 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs1303257964; called by muse, mutect2, varscan2
- PLAAT1 | c.807_808del p.R269Sfs*47 (on ENST00000650797; = p.R164Sfs*47 on NM_020386.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 25/241 reads (10%) | catalogued as rs761355652; called by pindel, varscan2
- PLAGL2 | c.1363G>A p.A455T | Missense Mutation (SNP) | VAF 99/500 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0.007); catalogued as rs1316740222; called by muse, mutect2, varscan2
- PLCB3 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 44/563 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748890795, COSV54191988, COSV99657540; called by muse, mutect2
- PLCG2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 48/387 reads (12%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1382212475, COSV100842414, COSV63869310; called by muse, mutect2, varscan2
- PLEC | c.12436C>T p.R4146C (on ENST00000322810 / NM_201380.4; = p.R4036C on NM_000445.5) | Missense Mutation (SNP) | VAF 22/627 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs989279969, COSV59599914; ClinVar: uncertain significance; called by muse, mutect2
- PLK3 | c.254G>T p.G85V | Missense Mutation (SNP) | VAF 67/423 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV64728820; called by muse, mutect2, varscan2
- PLPPR4 | c.2271del p.T758Hfs*8 | Frame Shift Del (DEL) | VAF 37/315 reads (12%) | catalogued as rs1557784793; called by mutect2, pindel, varscan2
- PMIS2 | c.68del p.P23Lfs*41 | Frame Shift Del (DEL) | VAF 72/466 reads (15%) | catalogued as rs1210084392; called by pindel, varscan2
- PML | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 71/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771660433, COSV51447716; called by muse, mutect2, varscan2
- PNCK | c.633del p.F212Sfs*14 (on ENST00000340888 / NM_001366975.1; = p.F295Sfs*14 on NM_001039582.3) | Frame Shift Del (DEL) | VAF 36/424 reads (8%) | catalogued as rs781891121, COSV61745231; called by mutect2, pindel
- PNPLA7 | c.3522del p.I1175Sfs*148 | Frame Shift Del (DEL) | VAF 64/449 reads (14%) | catalogued as rs761459630; called by mutect2, varscan2
- PNPLA7 | c.1649G>T p.S550I | Missense Mutation (SNP) | VAF 22/432 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as COSV52993721; called by muse, mutect2
- POFUT2 | c.799A>G p.I267V | Missense Mutation (SNP) | VAF 39/267 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1447153022; called by muse, mutect2, varscan2
- POGLUT3 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 64/366 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.158); catalogued as COSV100052483; called by muse, mutect2, varscan2
- POLD1 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 52/779 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs760077781; ClinVar: uncertain significance; called by muse, mutect2
- POLE3 | c.340del p.T114Qfs*32 | Frame Shift Del (DEL) | VAF 48/462 reads (10%) | catalogued as rs1340821595; called by mutect2, pindel
- POLM | c.290del p.P97Qfs*6 | Frame Shift Del (DEL) | VAF 90/488 reads (18%) | catalogued as rs745933237; called by mutect2, varscan2
- POMT1 | c.547del p.S183Lfs*2 | Frame Shift Del (DEL) | VAF 72/392 reads (18%) | catalogued as COSV104417508; called by mutect2, pindel, varscan2
- POTEI | c.2182del p.R728Gfs*16 | Frame Shift Del (DEL) | VAF 6/45 reads (13%) | catalogued as rs775721804; called by mutect2, varscan2
- POU5F1B | c.959G>A p.G320D | Missense Mutation (SNP) | VAF 84/994 reads (8%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.895); catalogued as rs780579414; called by muse, mutect2
- PPL | c.1209del p.V404Wfs*13 | Frame Shift Del (DEL) | VAF 83/538 reads (15%) | catalogued as COSV100631133; called by mutect2, pindel, varscan2
- PPP1R16B | c.1634del p.P545Hfs*3 | Frame Shift Del (DEL) | VAF 61/443 reads (14%) | catalogued as COSV55379747, COSV55380289; called by mutect2, pindel, varscan2
- PPP1R26 | c.3161del p.G1054Afs*100 | Frame Shift Del (DEL) | VAF 87/505 reads (17%) | catalogued as rs1554733377; called by mutect2, pindel, varscan2
- PROB1 | c.290G>A p.R97Q | Missense Mutation (SNP) | VAF 118/638 reads (18%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.003); catalogued as rs918862831; called by muse, mutect2, varscan2
- PRRT1B | c.203del p.G68Afs*123 | Frame Shift Del (DEL) | VAF 40/372 reads (11%) | catalogued as rs1290717087; called by mutect2, pindel, varscan2
- PRRT3 | c.1748T>C p.V583A | Missense Mutation (SNP) | VAF 58/588 reads (10%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs762158398; called by muse, mutect2
- PTF1A | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 52/462 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1339056661, COSV64735082; called by mutect2, varscan2
- PTPN13 | c.2713C>T p.R905* | Nonsense Mutation (SNP) | VAF 42/512 reads (8%) | catalogued as rs773296258, COSV57417233; called by muse, mutect2
- PTPN3 | c.2021del p.N674Tfs*28 | Frame Shift Del (DEL) | VAF 42/405 reads (10%) | catalogued as COSV52711823; called by mutect2, pindel, varscan2
- PTPRT | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 55/332 reads (17%) | SIFT tolerated (0.21); PolyPhen benign (0.28); catalogued as rs778928297, COSV61977204; called by muse, mutect2, varscan2
- PUS1 | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 63/438 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs559054645, COSV59036490; called by muse, mutect2, varscan2
- QRICH1 | c.1248G>A p.W416* | Nonsense Mutation (SNP) | VAF 91/536 reads (17%) | catalogued as COSV100676888; called by muse, varscan2
- RAB11FIP3 | c.668G>A p.R223H | Missense Mutation (SNP) | VAF 27/542 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.026); catalogued as COSV51933630; called by muse, mutect2
- RADIL | c.1783C>T p.R595C | Missense Mutation (SNP) | VAF 93/530 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs774854763, COSV68200117; called by muse, mutect2, varscan2
- RAI1 | c.3103del p.Q1035Rfs*29 | Frame Shift Del (DEL) | VAF 100/602 reads (17%) | catalogued as rs774789734; called by mutect2, pindel, varscan2
- RALGAPA2 | c.3287C>T p.A1096V | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as rs368408090; called by muse, varscan2
- RANBP9 | c.1819C>T p.R607C | Missense Mutation (SNP) | VAF 70/364 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs762168475, COSV99163500; called by muse, mutect2, varscan2
- RASAL1 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 56/401 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs199548072, COSV55657711; called by muse, mutect2, varscan2
- RBL1 | c.431del p.L144* | Frame Shift Del (DEL) | VAF 43/260 reads (17%) | catalogued as COSV60328025; called by mutect2, pindel, varscan2
- RBM25 | c.1261C>T p.R421W | Missense Mutation (SNP) | VAF 74/518 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.42); catalogued as rs750883608, COSV56198761; called by muse, mutect2, varscan2
- RBMXL3 | c.366del p.S123Lfs*153 | Frame Shift Del (DEL) | VAF 100/603 reads (17%) | catalogued as rs781840406, COSV57756886; called by mutect2, pindel, varscan2
- RBP3 | c.1153C>T p.L385F | Missense Mutation (SNP) | VAF 64/470 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs782387708; called by muse, mutect2, varscan2
- RELN | c.6402G>T p.E2134D | Missense Mutation (SNP) | VAF 79/496 reads (16%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.525); catalogued as rs1364095339; called by muse, mutect2, varscan2
- REV3L | c.6008G>A p.R2003Q | Missense Mutation (SNP) | VAF 62/347 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV62618370; called by muse, mutect2, varscan2
- REV3L | c.4751G>A p.R1584Q | Missense Mutation (SNP) | VAF 53/368 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs776259034, COSV62615906; called by muse, mutect2, varscan2
- RFX5 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 84/463 reads (18%) | catalogued as rs766158684, COSV51839942; called by muse, mutect2, varscan2
- RGMB | c.880C>T p.R294C (on ENST00000513185 / NM_001366508.1; = p.R335C on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 86/487 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1184192871; called by muse, mutect2, varscan2
- RGS9BP | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 76/458 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as rs1277979833; called by mutect2, varscan2
- RIOX1 | c.1619C>T p.A540V | Missense Mutation (SNP) | VAF 47/543 reads (9%) | SIFT tolerated (0.75); PolyPhen benign (0.055); catalogued as rs370838005; called by muse, mutect2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 32/236 reads (14%) | catalogued as rs757038390; called by mutect2, varscan2
- RPL6 | c.256_258del p.E86del | In Frame Del (DEL) | VAF 55/347 reads (16%) | catalogued as rs756314154; called by mutect2, pindel, varscan2
- RUNX3 | c.785G>A p.R262H | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs753201950; called by muse, mutect2, varscan2
- SACS | c.2174C>T p.A725V | Missense Mutation (SNP) | VAF 25/208 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV101207490; called by muse, mutect2, varscan2
- SAFB | c.2519del p.G840Afs*2 | Frame Shift Del (DEL) | VAF 79/534 reads (15%) | catalogued as COSV52649607; called by mutect2, pindel, varscan2
- SALL3 | c.3034C>T p.R1012* | Nonsense Mutation (SNP) | VAF 126/674 reads (19%) | catalogued as rs751879304, COSV101609972; called by muse, mutect2, varscan2
- SALL4 | c.2983del p.V995Ffs*14 | Frame Shift Del (DEL) | VAF 85/656 reads (13%) | catalogued as rs753320334; called by mutect2, pindel, varscan2
- SARAF | c.638G>A p.R213H | Missense Mutation (SNP) | VAF 42/356 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs200334339; called by muse, mutect2, varscan2
- SCARF1 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 51/760 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); catalogued as rs1340264658; called by muse, mutect2
- SCARF2 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 68/336 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1195611324; called by muse, mutect2, varscan2
- SCN11A | c.1370del p.K457Rfs*15 | Frame Shift Del (DEL) | VAF 36/254 reads (14%) | catalogued as COSV56572200; called by mutect2, varscan2
- SCN1B | c.625G>T p.E209* | Nonsense Mutation (SNP) | VAF 76/432 reads (18%) | catalogued as rs1555721527; called by muse, mutect2, varscan2
- SDC3 | c.1063C>T p.R355C | Missense Mutation (SNP) | VAF 110/575 reads (19%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.448); catalogued as rs372545406; called by muse, mutect2, varscan2
- SDK2 | c.370G>A p.V124I | Missense Mutation (SNP) | VAF 77/445 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs374727187; called by muse, mutect2, varscan2
- SEC14L6 | c.979C>T p.R327W | Missense Mutation (SNP) | VAF 91/551 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as rs200236380; called by muse, mutect2, varscan2
- SEC24C | c.1375dup p.Q459Pfs*17 | Frame Shift Ins (INS) | VAF 54/302 reads (18%) | catalogued as rs764652839; called by mutect2, varscan2
- SEC63 | c.1596A>T p.L532F | Missense Mutation (SNP) | VAF 46/298 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.202); catalogued as rs756336859, COSV64598351, COSV64602524; called by muse, varscan2
- SEPTIN12 | c.17G>A p.R6H | Missense Mutation (SNP) | VAF 34/380 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as rs746750799, COSV51615618; called by muse, mutect2
- SETD1B | c.23_24del p.H8Pfs*29 | Frame Shift Del (DEL) | VAF 40/284 reads (14%) | catalogued as rs1476636202; called by pindel, varscan2
- SGO1 | c.22A>G p.K8E | Missense Mutation (SNP) | VAF 28/208 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV55424857; called by muse, mutect2, varscan2
- SGSM3 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.67); catalogued as rs773465107, COSV99960062; called by muse, mutect2, varscan2
- SH2D7 | c.397C>T p.P133S | Missense Mutation (SNP) | VAF 63/404 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1466470540; called by muse, mutect2, varscan2
- SH3GLB2 | c.1080+1G>A p.X360_splice | Splice Site (SNP) | VAF 26/354 reads (7%) | catalogued as rs1421853555; called by muse, mutect2
- SH3TC1 | c.1381del p.Q461Rfs*15 | Frame Shift Del (DEL) | VAF 80/451 reads (18%) | catalogued as rs1278042780; called by mutect2, pindel, varscan2
- SHANK3 | c.4636G>A p.G1546R | Missense Mutation (SNP) | VAF 76/459 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.219); catalogued as rs1231950461; called by muse, mutect2, varscan2
- SHC1 | c.92dup p.E32Gfs*23 | Frame Shift Ins (INS) | VAF 76/536 reads (14%) | catalogued as rs752843778; called by mutect2, varscan2
- SHISA9 | c.131del p.G44Afs*72 | Frame Shift Del (DEL) | VAF 74/488 reads (15%) | catalogued as COSV101376111; called by mutect2, pindel, varscan2
- SLC10A2 | c.281C>T p.P94L | Missense Mutation (SNP) | VAF 85/426 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as rs139804161; called by muse, mutect2, varscan2
- SLC15A5 | c.410T>C p.L137P | Missense Mutation (SNP) | VAF 73/370 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.607); catalogued as rs1366914394; called by muse, mutect2
- SLC16A6 | c.527G>A p.R176H | Missense Mutation (SNP) | VAF 36/280 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs782479737, COSV59177747; called by muse, mutect2, varscan2
- SLC22A6 | c.777del p.F259Lfs*27 | Frame Shift Del (DEL) | VAF 56/430 reads (13%) | catalogued as rs749849908; called by mutect2, pindel, varscan2
- SLC25A13 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.819); catalogued as rs949468946, COSV55712881; called by muse, mutect2
- SLC25A2 | c.60del p.T21Qfs*5 | Frame Shift Del (DEL) | VAF 72/448 reads (16%) | catalogued as rs782785741; called by mutect2, pindel, varscan2
- SLC28A1 | c.795G>T p.Q265H | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs529925221; called by muse, mutect2, varscan2
- SLC35A2 | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 128/674 reads (19%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs782347244, COSV54430944; called by muse, mutect2, varscan2
- SLC39A4 | c.1703C>T p.T568M (on ENST00000301305 / NM_001374839.1; = p.T543M on NM_017767.3) | Missense Mutation (SNP) | VAF 61/524 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1554871980; called by muse, mutect2, varscan2
- SLC46A3 | c.816dup p.V273Cfs*13 | Frame Shift Ins (INS) | VAF 44/218 reads (20%) | catalogued as rs768002987; called by mutect2, varscan2
- SLC4A1 | c.515del p.G172Vfs*2 | Frame Shift Del (DEL) | VAF 44/340 reads (13%) | catalogued as COSV52263439; called by mutect2, varscan2
- SLC5A10 | c.1004C>T p.P335L (on ENST00000395645 / NM_001042450.4; = p.P351L on NM_152351.5) | Missense Mutation (SNP) | VAF 95/540 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs560313570; called by muse, mutect2, varscan2
- SLC6A3 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 105/577 reads (18%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.866); catalogued as rs760467074, COSV99548802; called by muse, mutect2, varscan2
- SLC7A3 | c.1142G>A p.R381H | Missense Mutation (SNP) | VAF 65/444 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs374563735, COSV53226623; called by muse, mutect2, varscan2
- SLCO4A1 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 57/311 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as rs745333263; called by muse, mutect2, varscan2
- SLIT1 | c.2237G>A p.R746Q | Missense Mutation (SNP) | VAF 100/544 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs758675702, COSV56590910; called by muse, mutect2, varscan2
- SMARCAL1 | c.2855C>T p.S952F | Missense Mutation (SNP) | VAF 38/180 reads (21%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as rs773963217; called by muse, mutect2, varscan2
- SMC2 | c.2251del p.T751Pfs*9 | Frame Shift Del (DEL) | VAF 27/152 reads (18%) | catalogued as rs1257129093; called by mutect2, pindel, varscan2
- SMCHD1 | c.1654C>T p.R552* | Nonsense Mutation (SNP) | VAF 22/164 reads (13%) | catalogued as rs1224850132; called by muse, mutect2, varscan2
- SMIM23 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 69/411 reads (17%) | SIFT tolerated, low confidence (0.13); PolyPhen probably damaging (0.98); catalogued as rs1055394176; called by muse, mutect2, varscan2
- SMO | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 67/325 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs765318599, COSV50824173, COSV50825282; called by muse, mutect2, varscan2
- SNAP91 | c.329del p.L110Wfs*15 | Frame Shift Del (DEL) | VAF 23/148 reads (16%) | catalogued as rs1254683145; called by mutect2, pindel, varscan2
- SNAPC1 | c.639dup p.D214* | Frame Shift Ins (INS) | VAF 28/240 reads (12%) | catalogued as rs778933382; called by mutect2, varscan2
- SNTG1 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.062); catalogued as COSV52444398; called by muse, mutect2, varscan2
- SOHLH2 | c.911del p.P304Lfs*8 | Frame Shift Del (DEL) | VAF 50/345 reads (14%) | catalogued as rs1270141379; called by mutect2, pindel, varscan2
- SORCS1 | c.310C>T p.R104C | Missense Mutation (SNP) | VAF 110/640 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV99547324; called by muse, mutect2, varscan2
- SORCS2 | c.1924C>T p.R642W | Missense Mutation (SNP) | VAF 96/550 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs373516909; called by muse, mutect2
- SOX13 | c.701del p.P234Qfs*41 | Frame Shift Del (DEL) | VAF 65/464 reads (14%) | catalogued as COSV65826761; called by mutect2, pindel, varscan2
- SPCS2 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.705); catalogued as rs770036983; called by muse, mutect2, varscan2
- SPPL2C | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 153/767 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs746773116; called by muse, mutect2, varscan2
- SPTBN2 | c.3170G>A p.R1057Q | Missense Mutation (SNP) | VAF 103/473 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.416); catalogued as rs771030742; called by muse, mutect2, varscan2
- SPZ1 | c.654del p.V219Sfs*23 | Frame Shift Del (DEL) | VAF 40/234 reads (17%) | catalogued as rs537342243; called by mutect2, varscan2
- SRGAP3 | c.2548dup p.V850Gfs*10 | Frame Shift Ins (INS) | VAF 60/374 reads (16%) | catalogued as rs759698239; called by mutect2, varscan2
- SRI | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 23/327 reads (7%) | catalogued as rs1422720493; called by muse, mutect2
- SRRD | c.1013C>T p.T338I | Missense Mutation (SNP) | VAF 10/282 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.015); catalogued as rs1277097266; called by muse, mutect2
- ST13 | c.1106C>T p.A369V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); catalogued as rs749274921, COSV53424044; called by muse, varscan2
- ST8SIA6 | c.753del p.A252Pfs*53 | Frame Shift Del (DEL) | VAF 23/183 reads (13%) | catalogued as rs758746672, COSV66468613; called by mutect2, varscan2
- STAMBPL1 | c.1214dup p.F407Lfs*55 | Frame Shift Ins (INS) | VAF 60/299 reads (20%) | catalogued as rs752994755; called by mutect2, varscan2
- STAU1 | c.1546G>A p.E516K (on ENST00000371856 / NM_001319135.1; = p.E435K on NM_004602.3) | Missense Mutation (SNP) | VAF 51/369 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs771314532, COSV61459152; called by muse, mutect2, varscan2
- STRN4 | c.595G>A p.V199I | Missense Mutation (SNP) | VAF 47/452 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs369741559; called by muse, mutect2, varscan2
- SULF1 | c.1370C>T p.P457L | Missense Mutation (SNP) | VAF 43/384 reads (11%) | SIFT tolerated (0.61); PolyPhen possibly damaging (0.52); catalogued as rs769376901, COSV52692331; called by muse, mutect2, varscan2
- SULT1C3 | c.526G>A p.V176I | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.473); catalogued as COSV61253439; called by muse, mutect2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 25/135 reads (19%) | catalogued as rs747003550; called by mutect2, varscan2
- SUN1 | c.1261C>T p.R421* (on ENST00000405266 / NM_001367651.1; = p.R301* on NM_025154.6 and 13 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 32/540 reads (6%) | catalogued as rs1221125460, COSV61778741; called by muse, mutect2
- SUV39H1 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 53/295 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as rs1395465056; called by muse, mutect2, varscan2
- SVOP | c.707G>A p.G236D | Missense Mutation (SNP) | VAF 72/419 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100139316; called by muse, mutect2, varscan2
- SYCP2 | c.3071del p.N1024Tfs*26 | Frame Shift Del (DEL) | VAF 34/194 reads (18%) | catalogued as rs753462162; called by mutect2, varscan2
- SYCP2 | c.2362del p.M788* | Frame Shift Del (DEL) | VAF 21/111 reads (19%) | catalogued as rs570102997; called by mutect2, varscan2
- SYDE1 | c.68del p.K23Sfs*74 | Frame Shift Del (DEL) | VAF 56/305 reads (18%) | catalogued as rs1257338693; called by mutect2, pindel, varscan2
- TACC2 | c.805T>C p.S269P | Missense Mutation (SNP) | VAF 54/556 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs774206095; called by muse, mutect2
- TACC2 | c.8059A>G p.M2687V (on ENST00000334433; = p.M765V on NM_006997.4) | Missense Mutation (SNP) | VAF 85/381 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.883); catalogued as COSV99588030; called by muse, mutect2, varscan2
- TADA1 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs373239463; called by muse, mutect2, varscan2
- TAF11L12 | c.583del p.I195Sfs*? | Frame Shift Del (DEL) | VAF 39/280 reads (14%) | catalogued as rs1482204329; called by mutect2, pindel, varscan2
- TANGO2 | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 73/462 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs776610669; called by muse, mutect2, varscan2
- TBC1D12 | c.1291C>T p.R431* | Nonsense Mutation (SNP) | VAF 27/227 reads (12%) | catalogued as rs572599039, COSV56552624; called by muse, mutect2, varscan2
- TBC1D16 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 69/381 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.255); catalogued as rs894428634; called by muse, mutect2, varscan2
- TBX6 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 64/396 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as rs758098097; called by muse, mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 38/305 reads (12%) | catalogued as rs758822980; called by mutect2, varscan2
- TDP1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 47/328 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs766476915; called by muse, mutect2, varscan2
- TEAD2 | c.883del p.H295Mfs*12 | Frame Shift Del (DEL) | VAF 54/342 reads (16%) | catalogued as rs763321097; called by mutect2, varscan2
- TEAD2 | c.607del p.Q203Kfs*29 | Frame Shift Del (DEL) | VAF 47/224 reads (21%) | catalogued as rs752700410; called by mutect2, pindel, varscan2
- TEX36 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 66/378 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64314846, COSV64315651; called by muse, mutect2, varscan2
- TGFBRAP1 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 67/341 reads (20%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs372720283; called by muse, mutect2, varscan2
- TGM5 | c.709G>A p.V237M (on ENST00000220420 / NM_201631.4; = p.V155M on NM_004245.4) | Missense Mutation (SNP) | VAF 15/388 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99589064; called by muse, mutect2
- THADA | c.2767C>T p.R923* | Nonsense Mutation (SNP) | VAF 37/460 reads (8%) | catalogued as rs1174263513, COSV57676761; called by muse, mutect2
- THBS2 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 82/476 reads (17%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.23); catalogued as rs769039736, COSV64680136; called by muse, mutect2, varscan2
- TICAM1 | c.1925dup p.P643Tfs*123 | Frame Shift Ins (INS) | VAF 50/384 reads (13%) | catalogued as rs762126373; called by mutect2, varscan2
- TMEM125 | c.340G>A p.A114T | Missense Mutation (SNP) | VAF 78/497 reads (16%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs756819583, COSV101443218; called by muse, varscan2
- TMEM132E | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 72/412 reads (17%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.018); catalogued as COSV100395851; called by muse, mutect2, varscan2
- TMEM272 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 53/372 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs751003881; called by muse, mutect2, varscan2
- TMTC1 | c.644C>T p.A215V (on ENST00000539277 / NM_001193451.2; = p.A107V on NM_175861.3) | Missense Mutation (SNP) | VAF 72/462 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767601505, COSV55487031; called by muse, mutect2, varscan2
- TMTC3 | c.1554dup p.Y519Ifs*8 | Frame Shift Ins (INS) | VAF 27/167 reads (16%) | catalogued as rs746894544; called by mutect2, pindel, varscan2
- TNFRSF1B | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 85/509 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); catalogued as rs754560287, COSV66164754; called by muse, mutect2, varscan2
- TNFRSF25 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 101/453 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.059); catalogued as rs372314459; called by muse, mutect2, varscan2
- TNXB | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 82/402 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs773546748; called by muse, mutect2, varscan2
- TOGARAM1 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 79/484 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV61889298; called by muse, mutect2, varscan2
- TOP2A | c.4303del p.R1435Gfs*13 | Frame Shift Del (DEL) | VAF 66/419 reads (16%) | catalogued as rs758129598; called by mutect2, pindel, varscan2
- TPGS1 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 72/433 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.015); catalogued as rs766527762; called by muse, mutect2, varscan2
- TPP1 | c.1417G>A p.G473R | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121908203, CM003661, COSV54990918; ClinVar: not provided; called by muse, mutect2, varscan2
- TRIM77 | c.453del p.K151Nfs*8 | Frame Shift Del (DEL) | VAF 27/134 reads (20%) | catalogued as rs553410308, COSV68065480; called by mutect2, varscan2
- TRIM9 | c.1759C>T p.R587C | Missense Mutation (SNP) | VAF 88/552 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs374121481; called by muse, mutect2, varscan2
- TRMT6 | c.458del p.K153Nfs*9 | Frame Shift Del (DEL) | VAF 16/80 reads (20%) | catalogued as rs780358338; called by mutect2, varscan2
- TRPV6 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 78/494 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs771513845, COSV63893857; called by muse, mutect2, varscan2
- TSSK1B | c.1075del p.Q359Nfs*43 | Frame Shift Del (DEL) | VAF 100/539 reads (19%) | catalogued as rs747842861, COSV101181233; called by mutect2, pindel, varscan2
- TTC28 | c.4237G>A p.G1413S | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); catalogued as rs374539679; called by muse, mutect2, varscan2
- TTN | c.48357A>C p.E16119D (on ENST00000591111; = p.E8695D on NM_003319.4) | Missense Mutation (SNP) | VAF 37/241 reads (15%) | PolyPhen benign (0.074); catalogued as COSV59905709; called by muse, mutect2, varscan2
- TTN | c.28568G>A p.R9523H (on ENST00000591111; = p.R8596H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/277 reads (12%) | PolyPhen probably damaging (0.998); catalogued as rs558220856, COSV60034029; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.25273C>A p.L8425I (on ENST00000591111; = p.L7498I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/327 reads (5%) | PolyPhen benign (0.175); catalogued as COSV60305775; called by muse, mutect2
- TUBGCP6 | c.4682_4683del p.V1561Afs*269 | Frame Shift Del (DEL) | VAF 70/473 reads (15%) | catalogued as rs1194927776; called by pindel, varscan2
- UBE4B | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 96/581 reads (17%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0); catalogued as rs746328640; called by muse, mutect2, varscan2
- UBTF | c.578C>T p.S193L | Missense Mutation (SNP) | VAF 66/406 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs532196673, COSV57186909; called by muse, mutect2, varscan2
- USH2A | c.14917G>A p.V4973M | Missense Mutation (SNP) | VAF 70/480 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs201426385; called by muse, mutect2, varscan2
- USP16 | c.1019del p.N340Ifs*24 | Frame Shift Del (DEL) | VAF 12/98 reads (12%) | catalogued as rs898552979; called by mutect2, pindel, varscan2
- USP26 | c.1836del p.G613Afs*26 | Frame Shift Del (DEL) | VAF 66/316 reads (21%) | catalogued as rs749830910; called by mutect2, varscan2
- VASN | c.370C>T p.R124W | Missense Mutation (SNP) | VAF 196/631 reads (31%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); catalogued as rs753678687; called by muse, mutect2, varscan2
- VEGFD | c.41_43del p.L14del | In Frame Del (DEL) | VAF 40/316 reads (13%) | catalogued as rs1314059450; called by pindel, varscan2
- VEPH1 | c.1661del p.N554Tfs*5 | Frame Shift Del (DEL) | VAF 37/190 reads (19%) | catalogued as rs756863093; called by mutect2, varscan2
- VIRMA | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 58/436 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1563464106; called by muse, mutect2, varscan2
- VRK2 | c.724C>T p.R242W | Missense Mutation (SNP) | VAF 75/382 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs779052033, COSV60875292; called by muse, mutect2, varscan2
- VSTM1 | c.709T>C p.*237Qext*8 | Nonstop Mutation (SNP) | VAF 30/460 reads (7%) | catalogued as rs758061019; called by muse, mutect2
- WDR31 | c.803G>A p.R268Q (on ENST00000374193 / NM_001006615.3; = p.R267Q on NM_145241.5) | Missense Mutation (SNP) | VAF 67/318 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.074); catalogued as rs373131738, COSV59145656; called by muse, mutect2, varscan2
- WDR33 | c.1944dup p.P649Afs*50 | Frame Shift Ins (INS) | VAF 90/570 reads (16%) | catalogued as rs1384471245; called by mutect2, pindel, varscan2
- WDR46 | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 46/552 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs779110677, COSV65842684; called by muse, mutect2
- WDR5 | c.648dup p.V217Rfs*42 | Frame Shift Ins (INS) | VAF 36/254 reads (14%) | catalogued as rs780890680; called by mutect2, varscan2
- WNK2 | c.4892G>A p.R1631H (on ENST00000297954 / NM_001282394.1; = p.R1594H on NM_006648.3) | Missense Mutation (SNP) | VAF 93/586 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs765224623, COSV104401301, COSV52953236; called by muse, mutect2, varscan2
- WNT1 | c.506del p.G169Afs*30 | Frame Shift Del (DEL) | VAF 156/626 reads (25%) | catalogued as COSV53295493; called by mutect2, pindel, varscan2
- WWC3 | c.874C>T p.R292C | Missense Mutation (SNP) | VAF 95/523 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.861); catalogued as rs750131978, COSV101081982; called by muse, mutect2, varscan2
- WWC3 | c.2923G>A p.A975T | Missense Mutation (SNP) | VAF 130/603 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1391068523; called by muse, mutect2, varscan2
- XKR6 | c.274del p.D92Tfs*73 | Frame Shift Del (DEL) | VAF 57/255 reads (22%) | catalogued as rs1403895317; called by mutect2, pindel, varscan2
- YAP1 | c.147del p.A50Pfs*24 | Frame Shift Del (DEL) | VAF 83/516 reads (16%) | catalogued as rs1555075353; called by mutect2, pindel, varscan2
- YLPM1 | c.2843C>T p.A948V | Missense Mutation (SNP) | VAF 64/442 reads (14%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs772590374; called by muse, varscan2
- YTHDF1 | c.27G>T p.Q9H | Missense Mutation (SNP) | VAF 61/406 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as rs1163574925; called by muse, mutect2, varscan2
- ZBED6 | c.234del p.K78Nfs*2 | Frame Shift Del (DEL) | VAF 59/393 reads (15%) | catalogued as rs1558085915; called by mutect2, pindel, varscan2
- ZBTB7C | c.403del p.E135Rfs*87 | Frame Shift Del (DEL) | VAF 109/509 reads (21%) | catalogued as rs747456682, COSV59688820; called by mutect2, pindel, varscan2
- ZDBF2 | c.5184del p.K1728Nfs*5 | Frame Shift Del (DEL) | VAF 51/400 reads (13%) | catalogued as rs745875253; called by mutect2, varscan2
- ZDHHC11B | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 24/273 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1414902920; called by muse, mutect2, varscan2
- ZFR | c.1074del p.E359Kfs*4 | Frame Shift Del (DEL) | VAF 50/242 reads (21%) | catalogued as rs751974853; called by mutect2, varscan2
- ZHX2 | c.1310del p.P437Rfs*15 | Frame Shift Del (DEL) | VAF 96/684 reads (14%) | catalogued as rs1563602910; called by mutect2, pindel, varscan2
- ZMIZ1 | c.1183C>G p.P395A | Missense Mutation (SNP) | VAF 87/561 reads (16%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV57889692; called by muse, mutect2, varscan2
- ZMYND10 | c.481del p.E161Rfs*18 | Frame Shift Del (DEL) | VAF 94/555 reads (17%) | catalogued as COSV51601018; called by mutect2, pindel, varscan2
- ZNF215 | c.1114del p.S372Vfs*5 | Frame Shift Del (DEL) | VAF 48/228 reads (21%) | catalogued as rs769655515; called by mutect2, pindel, varscan2
- ZNF253 | c.342del p.G115Afs*22 | Frame Shift Del (DEL) | VAF 25/182 reads (14%) | catalogued as rs774038489; called by mutect2, varscan2
- ZNF347 | c.1414C>A p.L472I | Missense Mutation (SNP) | VAF 65/431 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV100498400; called by muse, mutect2, varscan2
- ZNF407 | c.5675C>T p.T1892M | Missense Mutation (SNP) | VAF 103/502 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs756687783; called by muse, mutect2, varscan2
- ZNF469 | c.36del p.T13Pfs*2 | Frame Shift Del (DEL) | VAF 73/446 reads (16%) | catalogued as rs1350473091; called by mutect2, pindel, varscan2
- ZNF48 | c.745del p.R249Dfs*43 | Frame Shift Del (DEL) | VAF 90/542 reads (17%) | catalogued as rs780189754; called by mutect2, pindel, varscan2
- ZNF648 | c.1541G>A p.R514H | Missense Mutation (SNP) | VAF 97/545 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs868122303, COSV60571403; called by muse, mutect2, varscan2
- ZNF677 | c.737A>G p.Y246C | Missense Mutation (SNP) | VAF 32/193 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as COSV61720564; called by muse, mutect2, varscan2
- ZNF707 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 138/793 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.756); catalogued as rs569187572, COSV62310955; called by muse, mutect2, varscan2
- ZNF765 | c.1082G>A p.G361D | Missense Mutation (SNP) | VAF 37/315 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.101); catalogued as COSV101125442, COSV67182953; called by muse, mutect2, varscan2
- ZNF793 | c.100C>T p.R34W | Missense Mutation (SNP) | VAF 68/453 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs763972983, COSV71324847; called by muse, mutect2, varscan2
- ZNF814 | c.1218dup p.H407Tfs*3 | Frame Shift Ins (INS) | VAF 42/316 reads (13%) | catalogued as rs755593872; called by mutect2, pindel, varscan2
- ZSCAN22 | c.811C>T p.R271C | Missense Mutation (SNP) | VAF 82/433 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs1239737957, COSV61638596; called by muse, mutect2, varscan2
- ZSCAN5B | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 78/460 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.084); catalogued as rs1354431723, COSV62839763; called by muse, mutect2, varscan2
- ABCA2 | c.4509G>A p.M1503I (on ENST00000614293; = p.M1473I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 82/514 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); called by muse, mutect2, varscan2
- ABCA5 | c.1202T>G p.I401S | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.16); called by muse, mutect2, varscan2
- ABCC3 | c.223-1G>T p.X75_splice | Splice Site (SNP) | VAF 72/327 reads (22%) | called by muse, mutect2, varscan2
- ABCC6 | c.460C>T p.Q154* | Nonsense Mutation (SNP) | VAF 43/393 reads (11%) | called by muse, mutect2, varscan2
- ABCG1 | c.602T>C p.L201P | Missense Mutation (SNP) | VAF 50/389 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.1672A>G p.T558A | Missense Mutation (SNP) | VAF 109/527 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AC099489.1 | c.8897A>G p.D2966G | Missense Mutation (SNP) | VAF 34/550 reads (6%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.911); called by muse, mutect2
- ACAD11 | c.1196del p.K399Rfs*3 | Frame Shift Del (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- ACAN | c.363G>T p.Q121H | Missense Mutation (SNP) | VAF 85/566 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- ACKR4 | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 37/434 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.357); called by muse, mutect2
- ACO1 | c.2341G>A p.D781N | Missense Mutation (SNP) | VAF 33/387 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS8 | c.1238T>C p.L413P | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- ADAMTSL5 | c.547T>C p.C183R | Missense Mutation (SNP) | VAF 77/441 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADCY8 | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 54/634 reads (9%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2
- ADGRE1 | c.160T>A p.Y54N | Missense Mutation (SNP) | VAF 28/495 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRG4 | c.8218G>A p.E2740K | Missense Mutation (SNP) | VAF 23/315 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.72); called by muse, mutect2
- ADGRL2 | c.4265G>A p.C1422Y (on ENST00000370717 / NM_001366005.1; = p.C1366Y on NM_012302.4) | Missense Mutation (SNP) | VAF 26/426 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ADH7 | c.79C>A p.L27I | Missense Mutation (SNP) | VAF 50/267 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- AEBP1 | c.2003T>C p.L668P | Missense Mutation (SNP) | VAF 69/414 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AFG3L2 | c.2372del p.P791Rfs*50 | Frame Shift Del (DEL) | VAF 54/379 reads (14%) | called by mutect2, pindel, varscan2
- AGAP3 | c.67dup p.Q23Pfs*71 (on ENST00000622464; = p.Q59Pfs*71 on NM_031946.7 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 42/230 reads (18%) | called by mutect2, varscan2
- AGL | c.2668del p.I890Ffs*10 | Frame Shift Del (DEL) | VAF 30/211 reads (14%) | called by mutect2, pindel, varscan2
- AGO1 | c.575del p.G192Vfs*20 | Frame Shift Del (DEL) | VAF 77/549 reads (14%) | called by mutect2, pindel, varscan2
- AGO2 | c.1065del p.K355Nfs*2 | Frame Shift Del (DEL) | VAF 46/371 reads (12%) | called by mutect2, pindel, varscan2
- AGTR2 | c.875T>G p.V292G | Missense Mutation (SNP) | VAF 98/536 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by mutect2, varscan2
- AKR1D1 | c.144dup p.Y49Vfs*5 | Frame Shift Ins (INS) | VAF 46/397 reads (12%) | called by pindel, varscan2
- AKR1D1 | c.763G>A p.A255T | Missense Mutation (SNP) | VAF 25/452 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.027); called by muse, mutect2
- AL645922.1 | c.1375_1376del p.S459Cfs*16 | Frame Shift Del (DEL) | VAF 76/453 reads (17%) | called by pindel, varscan2
- ALPK3 | c.2757del p.T920Lfs*38 | Frame Shift Del (DEL) | VAF 82/550 reads (15%) | called by mutect2, pindel, varscan2
- AMIGO1 | c.518T>C p.F173S | Missense Mutation (SNP) | VAF 45/589 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- AMIGO3 | c.1148del p.T383Kfs*47 | Frame Shift Del (DEL) | VAF 75/547 reads (14%) | called by mutect2, pindel, varscan2
- ANAPC4 | c.1254del p.R419Gfs*8 | Frame Shift Del (DEL) | VAF 25/149 reads (17%) | called by mutect2, pindel, varscan2
- ANAPC5 | c.1540del p.I514Yfs*7 | Frame Shift Del (DEL) | VAF 22/166 reads (13%) | called by pindel, varscan2
- ANGPT1 | c.572del p.N191Tfs*4 | Frame Shift Del (DEL) | VAF 22/168 reads (13%) | called by mutect2, pindel, varscan2
- ANGPTL2 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 71/464 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK3 | c.7668G>T p.W2556C | Missense Mutation (SNP) | VAF 81/456 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ANKRD24 | c.2830G>T p.G944C | Missense Mutation (SNP) | VAF 60/660 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); called by muse, mutect2
- ANKRD26 | c.4361T>C p.L1454S | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- AP3B2 | c.974C>T p.A325V | Missense Mutation (SNP) | VAF 83/476 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- AP5Z1 | c.807G>T p.Q269H | Missense Mutation (SNP) | VAF 28/468 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.532); called by muse, mutect2
- APC2 | c.6312C>A p.H2104Q | Missense Mutation (SNP) | VAF 55/347 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- APLP1 | c.65T>C p.L22P | Missense Mutation (SNP) | VAF 72/483 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- APOO | c.292G>T p.D98Y | Missense Mutation (SNP) | VAF 41/223 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); called by muse, mutect2, varscan2
- ARC | c.419G>A p.G140D | Missense Mutation (SNP) | VAF 109/737 reads (15%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ARFGEF3 | c.3406G>A p.A1136T | Missense Mutation (SNP) | VAF 45/333 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.194); called by muse, mutect2, varscan2
- ARHGAP28 | c.1411T>C p.F471L (on ENST00000383472 / NM_001366230.1; = p.F312L on NM_001010000.3) | Missense Mutation (SNP) | VAF 10/272 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.099); called by muse, mutect2
- ARHGAP29 | c.2827del p.I943Ffs*18 | Frame Shift Del (DEL) | VAF 21/172 reads (12%) | called by pindel, varscan2
- ARHGAP39 | c.242A>T p.Y81F | Missense Mutation (SNP) | VAF 99/652 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARHGEF17 | c.1850del p.P617Lfs*10 | Frame Shift Del (DEL) | VAF 86/470 reads (18%) | called by pindel, varscan2
- ARHGEF39 | c.371del p.N124Ifs*41 | Frame Shift Del (DEL) | VAF 51/324 reads (16%) | called by mutect2, pindel, varscan2
- ARID1A | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 32/642 reads (5%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- ARID5B | c.2215C>A p.Q739K | Missense Mutation (SNP) | VAF 64/405 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ARMC6 | c.653A>G p.K218R (on ENST00000392336; = p.K193R on NM_033415.4) | Missense Mutation (SNP) | VAF 86/511 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- ASPH | c.903dup p.P302Sfs*14 | Frame Shift Ins (INS) | VAF 20/182 reads (11%) | called by mutect2, pindel, varscan2
- ASPHD1 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 87/497 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ATP1B4 | c.436A>G p.T146A (on ENST00000218008 / NM_001142447.3; = p.T142A on NM_012069.5) | Missense Mutation (SNP) | VAF 48/374 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- ATP6V1A | c.329G>A p.S110N | Missense Mutation (SNP) | VAF 22/318 reads (7%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- ATXN3L | c.544A>G p.S182G | Missense Mutation (SNP) | VAF 62/447 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, varscan2
- AXIN2 | c.2421dup p.A808Sfs*4 | Frame Shift Ins (INS) | VAF 64/313 reads (20%) | called by mutect2, pindel, varscan2
- AZI2 | c.875G>A p.G292D | Missense Mutation (SNP) | VAF 65/389 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- B3GNT4 | c.59dup p.L20Ffs*65 | Frame Shift Ins (INS) | VAF 39/340 reads (11%) | called by pindel, varscan2
- BACH2 | c.192G>T p.Q64H | Missense Mutation (SNP) | VAF 18/536 reads (3%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); called by muse, mutect2
- BAG4 | c.1147dup p.I383Nfs*12 | Frame Shift Ins (INS) | VAF 48/385 reads (12%) | called by mutect2, varscan2
- BAX | c.474+2T>C p.X158_splice (on ENST00000345358 / NM_001291428.2; = p.V159A on NM_004324.4) | Splice Site (SNP) | VAF 31/486 reads (6%) | called by muse, mutect2
- BBS12 | c.809A>G p.E270G | Missense Mutation (SNP) | VAF 82/469 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- BCL11A | c.976del p.L326Sfs*61 (on ENST00000335712 / NM_001365609.1; = p.L360Sfs*61 on NM_018014.4) | Frame Shift Del (DEL) | VAF 42/321 reads (13%) | called by mutect2, pindel, varscan2
- BCL3 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 18/430 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- BCL9L | c.2786T>C p.M929T | Missense Mutation (SNP) | VAF 95/546 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- BCLAF1 | c.2411G>A p.G804D | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BEND4 | c.264del p.G91Afs*23 | Frame Shift Del (DEL) | VAF 58/450 reads (13%) | called by pindel, varscan2
- BNIP3L | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 72/492 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- BNIP5 | c.937del p.A313Lfs*109 | Frame Shift Del (DEL) | VAF 109/645 reads (17%) | called by mutect2, pindel, varscan2
- BPIFB1 | c.178A>G p.S60G | Missense Mutation (SNP) | VAF 65/448 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRD3 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 98/609 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- BRF1 | c.860A>C p.E287A | Missense Mutation (SNP) | VAF 74/376 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- BRMS1 | c.321del p.L108Cfs*22 | Frame Shift Del (DEL) | VAF 54/416 reads (13%) | called by mutect2, pindel, varscan2
- BRPF1 | c.1461G>T p.K487N | Missense Mutation (SNP) | VAF 40/641 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.368); called by muse, mutect2
- BTBD17 | c.1157C>T p.P386L | Missense Mutation (SNP) | VAF 40/560 reads (7%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- BTBD8 | c.823dup p.T275Nfs*2 | Frame Shift Ins (INS) | VAF 28/187 reads (15%) | called by mutect2, pindel, varscan2
- BTD | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 61/379 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BX276092.9 | c.7T>A p.S3T | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- C1QL1 | c.172G>A p.A58T | Missense Mutation (SNP) | VAF 108/494 reads (22%) | SIFT tolerated (0.41); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- C3orf56 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 50/344 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- C4orf54 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 36/542 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2
- C8orf48 | c.310G>C p.D104H | Missense Mutation (SNP) | VAF 62/404 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- C9orf78 | c.578C>T p.A193V | Missense Mutation (SNP) | VAF 64/431 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- CA7 | c.449del p.L150Wfs*10 | Frame Shift Del (DEL) | VAF 61/396 reads (15%) | called by mutect2, pindel, varscan2
- CABYR | c.530C>A p.A177D | Missense Mutation (SNP) | VAF 64/358 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CACNA1C | c.6011C>A p.A2004E (on ENST00000399634 / NM_001167625.1; = p.A1933E on NM_000719.7) | Missense Mutation (SNP) | VAF 58/381 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CALHM5 | c.738del p.F246Lfs*75 | Frame Shift Del (DEL) | VAF 47/386 reads (12%) | called by mutect2, varscan2
- CAMTA2 | c.2615_2616del p.S872* | Frame Shift Del (DEL) | VAF 70/533 reads (13%) | called by pindel, varscan2
- CARD18 | c.39dup p.I14Yfs*20 | Frame Shift Ins (INS) | VAF 43/271 reads (16%) | called by mutect2, pindel, varscan2
- CARMIL1 | c.2627C>T p.P876L | Missense Mutation (SNP) | VAF 57/339 reads (17%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- CARMIL2 | c.1254del p.Q419Sfs*93 | Frame Shift Del (DEL) | VAF 67/426 reads (16%) | called by mutect2, pindel, varscan2
- CASP8 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
1,188 further variants in this file (668 protein-altering or splice-affecting, 447 silent, 73 other) are not listed here.
